Somatic mutation profile of tumor specimen 0DVZEH from CCDI case PBCMJN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; Age at diagnosis: 14.9 years (5,436 days).
Specimen 0DVZEH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c4aec166-6d36-402b-8b7a-0daf49f5a3c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVZEA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f178e449-e514-46e8-b236-dbc698487cb6

The open-access MAF lists 1,129 somatic variants for this specimen: 662 protein-altering or splice-affecting, 268 silent, 199 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 585, Silent 268, Intron 113, 3'UTR 49, Nonsense Mutation 31, 5'UTR 26, Splice Region 15, Splice Site 14, Frame Shift Del 11, RNA 6, Frame Shift Ins 5, 3'Flank 3.

Variants (750 of 1,129; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2626C>T p.R876* | Nonsense Mutation (SNP) | VAF 254/1010 reads (25%) | hotspot (GDC flag); catalogued as rs121913333, CM942020, COSV57320538; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- DCX | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 43/433 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs587783562, CM980528, COSV57565678; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DPF2 | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 171/724 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs1555032051, COSV52888106; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.2524G>A p.V842I | Missense Mutation (SNP) | VAF 201/765 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1057519738, COSV104371920, COSV54062791; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ERCC6 | c.2923C>T p.R975* | Nonsense Mutation (SNP) | VAF 82/320 reads (26%) | catalogued as rs772801089, COSV63388840; ClinVar: pathogenic; called by muse, varscan2
- KCNC1 | c.1294G>A p.V432M | Missense Mutation (SNP) | VAF 102/329 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1057524670, COSV99789060; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 130/566 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PDYN | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 134/271 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201486601, CM107860, COSV54101259; ClinVar: pathogenic; called by muse, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 171/644 reads (27%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TGFBR2 | c.1336G>A p.D446N | Missense Mutation (SNP) | VAF 198/702 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs886039551, CM060085, CM086981, COSV55445539, COSV55457221; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 115/386 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC12 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 187/889 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.03); catalogued as rs543162145, COSV100252768; called by muse, mutect2, varscan2
- ABCC8 | c.3329+7G>A | Splice Region (SNP) | VAF 132/585 reads (23%) | catalogued as rs776313489; called by muse, mutect2, varscan2
- ABCG8 | c.1649C>T p.A550V | Missense Mutation (SNP) | VAF 96/276 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs202028007, COSV99699353; called by muse, mutect2, varscan2
- ABHD1 | c.395C>T p.T132I | Missense Mutation (SNP) | VAF 59/1020 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.351); catalogued as rs750860041; called by muse, mutect2
- ABL1 | c.2089C>T p.R697C | Missense Mutation (SNP) | VAF 95/368 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.772); catalogued as rs769147225; called by muse, mutect2, varscan2
- ACACA | c.4087C>T p.R1363C | Missense Mutation (SNP) | VAF 52/417 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs780539614; called by muse, mutect2, varscan2
- ACLY | c.1525G>A p.V509M | Missense Mutation (SNP) | VAF 81/573 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1041624299, COSV61252060; called by muse, mutect2, varscan2
- ACSM3 | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 190/925 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs755776881; called by muse, mutect2, varscan2
- ADAMTS7 | c.2413G>A p.E805K | Missense Mutation (SNP) | VAF 124/453 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as rs776433742; called by muse, varscan2
- ADCY9 | c.3814C>T p.R1272W | Missense Mutation (SNP) | VAF 261/777 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs371680928; called by muse, mutect2, varscan2
- ADD3 | c.1400C>T p.T467M | Missense Mutation (SNP) | VAF 101/336 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.11); catalogued as COSV53324836; called by muse, mutect2, varscan2
- ADGB | c.791C>G p.T264R | Missense Mutation (SNP) | VAF 97/514 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV58861714; called by muse, mutect2, varscan2
- AGPAT1 | c.83G>A p.C28Y | Missense Mutation (SNP) | VAF 59/502 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1277567457; called by muse, varscan2
- AKAP17A | c.2027G>A p.R676H | Missense Mutation (SNP) | VAF 127/630 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.32); catalogued as rs774253177; called by muse, mutect2, varscan2
- ALDH1L2 | c.757C>T p.P253S | Missense Mutation (SNP) | VAF 58/722 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV51555115; called by muse, mutect2
- ANAPC2 | c.1063C>T p.R355W | Missense Mutation (SNP) | VAF 55/212 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs1347684871; called by muse, mutect2, varscan2
- ANKRD44 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 120/456 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs568552922; called by muse, mutect2, varscan2
- AOX1 | c.2786C>T p.A929V | Missense Mutation (SNP) | VAF 181/775 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs746986816; called by muse, mutect2, varscan2
- ARFGAP3 | c.1394C>T p.P465L | Missense Mutation (SNP) | VAF 151/664 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.036); catalogued as rs746672024; called by muse, mutect2, varscan2
- ARHGAP35 | c.2066G>A p.R689Q | Missense Mutation (SNP) | VAF 59/216 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.388); catalogued as rs142807428; called by muse, varscan2
- ARHGEF10 | c.3347C>T p.A1116V (on ENST00000398564; = p.A1091V on NM_014629.4) | Missense Mutation (SNP) | VAF 44/548 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs769153898, COSV100033639; called by muse, mutect2
- ARHGEF4 | c.2065C>T p.R689C | Missense Mutation (SNP) | VAF 101/457 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs367890416, COSV100388796; called by muse, mutect2, varscan2
- ARID1B | c.2132C>T p.A711V | Missense Mutation (SNP) | VAF 76/321 reads (24%) | SIFT tolerated, low confidence (0.29); PolyPhen possibly damaging (0.742); catalogued as rs563771544, COSV51673928; called by muse, mutect2, varscan2
- ARID3B | c.1136G>A p.R379Q | Missense Mutation (SNP) | VAF 170/594 reads (29%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.478); catalogued as rs762464589, COSV60558050; called by muse, varscan2
- ARID5A | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 96/785 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs150447575; called by muse, mutect2, varscan2
- ARMC10 | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 178/1000 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs774834954; called by muse, varscan2
- ASH2L | c.1012A>G p.K338E | Missense Mutation (SNP) | VAF 177/853 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV51699455; called by muse, mutect2, varscan2
- ASMTL | c.1123G>A p.G375S | Missense Mutation (SNP) | VAF 422/1095 reads (39%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.718); catalogued as rs199829721, COSV67244780; called by muse, varscan2
- ASXL2 | c.1922G>A p.R641H | Missense Mutation (SNP) | VAF 191/856 reads (22%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.977); catalogued as rs1338721842; called by muse, varscan2
- ATP13A5 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 136/587 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs776380026, COSV60868282; called by muse, mutect2, varscan2
- ATP2A3 | c.1211G>A p.C404Y | Missense Mutation (SNP) | VAF 37/188 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs1360500626; called by muse, mutect2, varscan2
- AUTS2 | c.1528C>T p.R510C | Missense Mutation (SNP) | VAF 113/479 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs930597957; called by muse, mutect2, varscan2
- AXL | c.2066C>T p.A689V (on ENST00000301178 / NM_021913.5; = p.A680V on NM_001699.6) | Missense Mutation (SNP) | VAF 199/792 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1420547997, COSV56565709; called by muse, mutect2, varscan2
- BAHCC1 | c.6553C>T p.R2185C | Missense Mutation (SNP) | VAF 105/354 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as rs781855634; called by muse, mutect2, varscan2
- BAX | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 122/519 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs751678403; called by mutect2, varscan2
- BAX | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 125/498 reads (25%) | catalogued as rs754446832, COSV53168935, COSV53169102; called by muse, mutect2, varscan2
- BORA | c.1381C>T p.R461W (on ENST00000613797; = p.R386W on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 92/665 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs779914917, COSV100909741; called by muse, mutect2, varscan2
- C11orf42 | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 46/624 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs989444083; called by muse, mutect2
- C16orf70 | c.697C>T p.R233W | Missense Mutation (SNP) | VAF 145/719 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs918765443; called by muse, mutect2, varscan2
- C7 | c.148C>T p.R50W | Missense Mutation (SNP) | VAF 326/876 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs376674018; called by muse, varscan2
- CABLES1 | c.89A>C p.Q30P | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs989185111; called by mutect2, varscan2
- CACNA1G | c.2509C>T p.R837C | Missense Mutation (SNP) | VAF 67/297 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61736294; called by muse, mutect2, varscan2
- CACNA2D4 | c.1042G>A p.V348I | Missense Mutation (SNP) | VAF 154/587 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773531067, COSV54953485; called by muse, mutect2, varscan2
- CACNG2 | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 126/491 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs759775990; called by muse, mutect2, varscan2
- CAMK2B | c.1112C>T p.T371M | Missense Mutation (SNP) | VAF 100/458 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.198); catalogued as rs918980747; called by muse, varscan2
- CASZ1 | c.4244G>A p.R1415Q | Missense Mutation (SNP) | VAF 154/634 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.905); catalogued as rs373591122; called by muse, varscan2
- CBLN3 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 37/449 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs562291434, COSV99249693; called by muse, mutect2
- CCDC88B | c.253G>A p.G85R | Missense Mutation (SNP) | VAF 158/616 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.324); catalogued as rs1282943359; called by muse, mutect2, varscan2
- CCN3 | c.312G>A p.A104= | Splice Region (SNP) | VAF 107/369 reads (29%) | catalogued as rs557684887, COSV52383129, COSV99423387; called by muse, mutect2, varscan2
- CCNF | c.721C>A p.L241I | Missense Mutation (SNP) | VAF 88/441 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.8); catalogued as COSV53543654; called by muse, mutect2, varscan2
- CD101 | c.112C>A p.P38T | Missense Mutation (SNP) | VAF 82/696 reads (12%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.767); catalogued as COSV56720936; called by muse, mutect2, varscan2
- CD109 | c.1522G>A p.A508T | Missense Mutation (SNP) | VAF 75/329 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.261); catalogued as rs1562056325, COSV54645086, COSV99752762; called by muse, varscan2
- CDCA7 | c.719G>A p.R240H (on ENST00000347703 / NM_145810.3; = p.R319H on NM_031942.5) | Missense Mutation (SNP) | VAF 211/750 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as rs544862695, COSV60719949; called by muse, mutect2, varscan2
- CDH10 | c.2296C>T p.R766* | Nonsense Mutation (SNP) | VAF 237/851 reads (28%) | catalogued as COSV100050202, COSV52579639, COSV52582699; called by muse, varscan2
- CDH16 | c.1630G>T p.G544C | Missense Mutation (SNP) | VAF 32/620 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100233719; called by muse, mutect2
- CDH3 | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 242/613 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50555023; called by muse, mutect2, varscan2
- CDH5 | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 193/856 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as rs145261593; called by muse, varscan2
- CDH5 | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 54/612 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs756929820, COSV58520490; called by muse, mutect2
- CDK1 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 89/400 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.795); catalogued as COSV57349413; called by muse, mutect2, varscan2
- CEACAM1 | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 195/797 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs148191044; called by muse, mutect2, varscan2
- CELA3A | c.415G>A p.V139I | Missense Mutation (SNP) | VAF 128/498 reads (26%) | SIFT tolerated (0.74); PolyPhen probably damaging (1); catalogued as rs533686702, COSV51583198; called by muse, varscan2
- CEMIP | c.3226G>A p.D1076N | Missense Mutation (SNP) | VAF 119/468 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as rs1159120769, COSV54997158; called by muse, mutect2, varscan2
- CEP170B | c.3901G>A p.G1301S (on ENST00000453495; = p.G1230S on NM_015005.3) | Missense Mutation (SNP) | VAF 63/307 reads (21%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.613); catalogued as rs775941430; called by muse, mutect2, varscan2
- CFAP57 | c.1819C>T p.R607C | Missense Mutation (SNP) | VAF 140/676 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as rs776669989, COSV65264556; called by muse, varscan2
- CFAP65 | c.782C>T p.T261M | Missense Mutation (SNP) | VAF 224/823 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.11); catalogued as rs568012659, COSV55390929; called by muse, mutect2, varscan2
- CFAP74 | c.3212C>T p.T1071M | Missense Mutation (SNP) | VAF 129/480 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as rs1464804260, COSV69038768; called by muse, mutect2, varscan2
- CGN | c.3098G>A p.R1033Q | Missense Mutation (SNP) | VAF 121/454 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372073643, COSV54972847; called by muse, mutect2, varscan2
- CHD4 | c.2399G>A p.R800H (on ENST00000357008 / NM_001363606.2; = p.R813H on NM_001273.5) | Missense Mutation (SNP) | VAF 148/604 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV58908829; called by muse, varscan2
- CHL1 | c.947T>C p.L316S (on ENST00000397491 / NM_001253387.1; = p.L332S on NM_006614.4) | Missense Mutation (SNP) | VAF 20/538 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.825); catalogued as COSV56601192; called by muse, mutect2
- CHMP6 | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 221/628 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as rs757260155; called by muse, mutect2, varscan2
- CIDEB | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 191/745 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs372963517; called by muse, mutect2, varscan2
- CLASP2 | c.4231G>A p.A1411T (on ENST00000359576; = p.A1410T on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 221/697 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs1392697482; called by muse, mutect2, varscan2
- CLCN4 | c.757C>T p.R253W | Missense Mutation (SNP) | VAF 223/341 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1250705466; called by muse, mutect2, varscan2
- CLCN6 | c.2199G>T p.E733D | Missense Mutation (SNP) | VAF 140/582 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.121); catalogued as COSV100412071; called by mutect2, varscan2
- CLTB | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 326/950 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs777822872, COSV60043875; called by muse, mutect2, varscan2
- COASY | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 63/1056 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776578070; called by muse, mutect2
- COL12A1 | c.8825G>A p.G2942D | Missense Mutation (SNP) | VAF 38/486 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59391939; called by muse, mutect2
- COL26A1 | c.835C>T p.Q279* (on ENST00000313669 / NM_001278563.3; = p.Q277* on NM_133457.4) | Nonsense Mutation (SNP) | VAF 153/574 reads (27%) | catalogued as COSV100561700; called by muse, mutect2, varscan2
- COL2A1 | c.2974A>T p.R992* | Nonsense Mutation (SNP) | VAF 107/410 reads (26%) | catalogued as CM053180; called by muse, varscan2
- COLQ | c.1205G>A p.R402H | Missense Mutation (SNP) | VAF 138/863 reads (16%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.905); catalogued as rs140670616; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COQ8B | c.1429C>T p.R477W | Missense Mutation (SNP) | VAF 64/254 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376652595; called by muse, mutect2, varscan2
- CRB1 | c.2795C>T p.P932L | Missense Mutation (SNP) | VAF 170/706 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs751958158, COSV66329391; called by muse, mutect2, varscan2
- CREBBP | c.3698G>T p.R1233M | Missense Mutation (SNP) | VAF 64/868 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99270741; called by muse, mutect2
- CROCC | c.718C>T p.R240* | Nonsense Mutation (SNP) | VAF 167/1102 reads (15%) | catalogued as rs779871764, COSV65011816; called by muse, mutect2, varscan2
- CSE1L | c.1643C>T p.P548L | Missense Mutation (SNP) | VAF 104/736 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs755611263; called by muse, varscan2
- CX3CL1 | c.677C>T p.T226I | Missense Mutation (SNP) | VAF 125/550 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.083); catalogued as rs552186852; called by muse, mutect2, varscan2
- CXCR2 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 139/528 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.26); catalogued as rs767538305, COSV59281728; called by muse, mutect2, varscan2
- DCDC2B | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 260/1013 reads (26%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.688); catalogued as rs1446834675; called by muse, mutect2, varscan2
- DCXR | c.692C>T p.T231M | Missense Mutation (SNP) | VAF 197/580 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761236094; called by muse, mutect2, varscan2
- DDIT3 | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 123/504 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1020049484, COSV56252149; called by muse, varscan2
- DEF6 | c.1138G>C p.E380Q | Missense Mutation (SNP) | VAF 54/232 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV57353237; called by muse, mutect2, varscan2
- DENND11 | c.982C>T p.R328W | Missense Mutation (SNP) | VAF 193/753 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as rs539927359; called by muse, mutect2, varscan2
- DHDH | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 171/715 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749797908, COSV55482608; called by muse, mutect2, varscan2
- DHX29 | c.1733G>A p.R578Q | Missense Mutation (SNP) | VAF 350/1105 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as rs750792920; called by muse, mutect2, varscan2
- DHX38 | c.3670C>T p.R1224C | Missense Mutation (SNP) | VAF 312/835 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs753324635; called by muse, mutect2, varscan2
- DIP2B | c.4445C>T p.S1482L | Missense Mutation (SNP) | VAF 195/752 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772210044, COSV56579943; called by muse, mutect2, varscan2
- DIS3L | c.2856+1G>A p.X952_splice (on ENST00000319212 / NM_001143688.3; = p.X869_splice on NM_133375.5 and 5 other RefSeq transcripts) | Splice Site (SNP) | VAF 99/376 reads (26%) | catalogued as rs965228164; called by muse, mutect2, varscan2
- DLL1 | c.1970C>T p.A657V | Missense Mutation (SNP) | VAF 59/519 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as rs780609795, COSV100816201; called by muse, mutect2, varscan2
- DNAAF5 | c.2483C>T p.T828M | Missense Mutation (SNP) | VAF 119/473 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.614); catalogued as rs1020266992, COSV99859307; called by muse, mutect2, varscan2
- DNAH10 | c.6665G>A p.R2222Q (on ENST00000409039; = p.R2161Q on NM_207437.3) | Missense Mutation (SNP) | VAF 218/799 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746998714; called by muse, mutect2, varscan2
- DNAH17 | c.12775G>T p.E4259* | Nonsense Mutation (SNP) | VAF 161/647 reads (25%) | catalogued as rs1174705131, COSV53147229; called by muse, mutect2, varscan2
- DNAH17 | c.12133G>A p.A4045T | Missense Mutation (SNP) | VAF 130/375 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as rs372342689, COSV67751956; called by muse, mutect2, varscan2
- DNAJA3 | c.502G>A p.G168S | Missense Mutation (SNP) | VAF 231/570 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as rs746432464; called by muse, mutect2, varscan2
- DNASE1 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 215/563 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs772385567; called by muse, varscan2
- DNER | c.1823C>T p.P608L | Missense Mutation (SNP) | VAF 126/515 reads (24%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs368405241, COSV59171289; called by muse, varscan2
- DOCK3 | c.4046G>A p.R1349H | Missense Mutation (SNP) | VAF 135/515 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1288220692, COSV56513145; called by muse, mutect2, varscan2
- DZIP1L | c.1771G>A p.A591T | Missense Mutation (SNP) | VAF 112/457 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760024871; called by muse, mutect2, varscan2
- ECT2L | c.2483G>A p.G828D | Missense Mutation (SNP) | VAF 250/916 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs1246714133; called by muse, mutect2, varscan2
- EDC4 | c.3425G>A p.R1142Q | Missense Mutation (SNP) | VAF 66/901 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs765430239; called by muse, mutect2
- ELFN1 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 64/308 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1302261656, COSV101300250; called by muse, mutect2, varscan2
- EP300 | c.3875-2A>G p.X1292_splice | Splice Site (SNP) | VAF 110/407 reads (27%) | catalogued as COSV54332454; called by muse, mutect2, varscan2
- EP400 | c.3901G>A p.E1301K | Missense Mutation (SNP) | VAF 206/717 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); catalogued as COSV57762384; called by muse, varscan2
- EPPK1 | c.4552C>T p.Q1518* | Nonsense Mutation (SNP) | VAF 22/313 reads (7%) | catalogued as rs1554660040; called by muse, mutect2
- ERBB3 | c.4025C>T p.T1342M | Missense Mutation (SNP) | VAF 95/359 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as rs140679673; called by muse, mutect2, varscan2
- ERCC6L2 | c.1031C>T p.T344M | Missense Mutation (SNP) | VAF 148/516 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs1411881441; called by muse, varscan2
- ERICH6 | c.976G>T p.D326Y | Missense Mutation (SNP) | VAF 110/881 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as rs746584101; called by muse, mutect2, varscan2
- ERO1A | c.1336G>A p.A446T | Missense Mutation (SNP) | VAF 84/299 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.643); catalogued as rs368708365; called by muse, mutect2, varscan2
- EXTL1 | c.667G>A p.G223R | Missense Mutation (SNP) | VAF 63/318 reads (20%) | SIFT tolerated (0.84); PolyPhen benign (0.006); catalogued as rs781198382, COSV65337157; called by muse, mutect2, varscan2
- F2 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 104/416 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1565702295, COSV61315661; called by muse, mutect2, varscan2
- FAM193A | c.2600G>A p.R867H | Missense Mutation (SNP) | VAF 150/579 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1257462018, COSV100219855; called by muse, mutect2, varscan2
- FAM20B | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 144/557 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as rs775553811; called by muse, mutect2, varscan2
- FANCA | c.2778C>T p.H926= | Splice Region (SNP) | VAF 88/528 reads (17%) | catalogued as rs765025976; called by muse, mutect2, varscan2
- FBXO38 | c.1109C>T p.A370V | Missense Mutation (SNP) | VAF 46/548 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.062); catalogued as rs779899138; called by muse, mutect2
- FBXO7 | c.521C>T p.S174L | Missense Mutation (SNP) | VAF 161/674 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as rs376455464; called by muse, mutect2, varscan2
- FBXW11 | c.175G>A p.V59I | Missense Mutation (SNP) | VAF 148/566 reads (26%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as rs775345069; called by muse, mutect2, varscan2
- FCGBP | c.7977G>T p.E2659D | Missense Mutation (SNP) | VAF 71/533 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.266); catalogued as rs1258500277; called by muse, mutect2, varscan2
- FCGBP | c.7183G>A p.D2395N | Missense Mutation (SNP) | VAF 83/496 reads (17%) | SIFT tolerated (0.82); PolyPhen benign (0.059); catalogued as rs1452761256; called by muse, mutect2, varscan2
- FER1L5 | c.5459C>T p.T1820I (on ENST00000623019; = p.T1784I on NM_001293083.2) | Missense Mutation (SNP) | VAF 203/722 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs1265046451; called by muse, mutect2, varscan2
- FKBP9 | c.1702G>A p.D568N | Missense Mutation (SNP) | VAF 101/412 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs762749018, COSV54227811, COSV54229232; called by muse, mutect2, varscan2
- FOXJ1 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 32/1146 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53943307; called by muse, mutect2
- FTMT | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 142/593 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as COSV58420388, COSV58421141; called by muse, varscan2
- GALNT18 | c.475G>A p.V159M | Missense Mutation (SNP) | VAF 166/641 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs759039128; called by muse, mutect2, varscan2
- GBP4 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 124/477 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.168); catalogued as rs771201733, COSV63254120; called by muse, mutect2, varscan2
- GGN | c.1400C>T p.P467L | Missense Mutation (SNP) | VAF 66/281 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.273); catalogued as rs1368962297; called by muse, mutect2, varscan2
- GIGYF1 | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 166/685 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1168010330; called by muse, mutect2, varscan2
- GOLGB1 | c.8643dup p.A2882Sfs*8 | Frame Shift Ins (INS) | VAF 112/461 reads (24%) | catalogued as rs1434973233; called by mutect2, varscan2
- GPBAR1 | c.365G>T p.G122V | Missense Mutation (SNP) | VAF 14/358 reads (4%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.955); catalogued as COSV99946519; called by muse, mutect2
- GPR21 | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 110/773 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.824); catalogued as rs142528272; called by muse, mutect2, varscan2
- GPR35 | c.763C>T p.R255C | Missense Mutation (SNP) | VAF 87/348 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs763867971, COSV60577448; called by muse, mutect2, varscan2
- GPRIN2 | c.1147C>T p.R383* | Nonsense Mutation (SNP) | VAF 78/656 reads (12%) | catalogued as rs376858389; called by muse, varscan2
- GRAMD1A | c.1684C>T p.R562W | Missense Mutation (SNP) | VAF 119/385 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs753306201; called by muse, mutect2, varscan2
- GRAMD4 | c.283+1G>A p.X95_splice | Splice Site (SNP) | VAF 72/648 reads (11%) | catalogued as COSV100730642, COSV63030847; called by muse, mutect2, varscan2
- GRIN2B | c.3544G>A p.G1182R | Missense Mutation (SNP) | VAF 150/490 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.131); catalogued as rs1248498963; called by muse, mutect2, varscan2
- GRM1 | c.1610G>A p.R537Q | Missense Mutation (SNP) | VAF 94/457 reads (21%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as rs1429236981, COSV51370927; called by muse, varscan2
- GSTCD | c.1372G>A p.V458I (on ENST00000360505 / NM_001031720.3; = p.V371I on NM_024751.3) | Missense Mutation (SNP) | VAF 155/589 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.672); catalogued as rs778300033; called by muse, mutect2, varscan2
- GTPBP1 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 39/694 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.588); catalogued as rs761281921, COSV53284130; called by muse, mutect2
- GXYLT1 | c.970G>A p.V324M | Missense Mutation (SNP) | VAF 61/351 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as rs780871656; called by muse, mutect2, varscan2
- HAUS5 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 118/475 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs760861854, COSV99178775; called by muse, mutect2, varscan2
- HECW2 | c.4556G>A p.G1519D | Missense Mutation (SNP) | VAF 41/879 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104369056; called by muse, mutect2
- HELZ2 | c.4048G>A p.A1350T (on ENST00000467148 / NM_001037335.2; = p.A781T on NM_033405.3) | Missense Mutation (SNP) | VAF 117/406 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.967); catalogued as rs376896320, COSV71295400; called by muse, mutect2, varscan2
- HERC2 | c.13688C>T p.A4563V | Missense Mutation (SNP) | VAF 64/770 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV55342224; called by muse, mutect2
- HMCN2 | c.2138A>G p.E713G | Missense Mutation (SNP) | VAF 113/513 reads (22%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.699); catalogued as COSV70279862; called by muse, varscan2
- HOMER2 | c.521C>T p.T174M (on ENST00000304231 / NM_199330.3; = p.T163M on NM_004839.4) | Missense Mutation (SNP) | VAF 152/574 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs761349827; called by muse, mutect2, varscan2
- HPS4 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 154/494 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs377042228; called by muse, mutect2, varscan2
- HPS4 | c.410C>T p.T137M | Missense Mutation (SNP) | VAF 147/593 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.156); catalogued as rs150403254, COSV61103584; called by muse, mutect2, varscan2
- HTT | c.9353T>C p.V3118A | Missense Mutation (SNP) | VAF 108/413 reads (26%) | SIFT tolerated (0.68); PolyPhen benign (0.077); catalogued as rs1380893520; called by muse, mutect2, varscan2
- ICE1 | c.5545C>T p.R1849C | Missense Mutation (SNP) | VAF 187/686 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs753732735, COSV56822229; called by muse, mutect2, varscan2
- IFT140 | c.2425C>T p.R809C | Missense Mutation (SNP) | VAF 85/451 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs755748472, COSV99559675; called by muse, mutect2, varscan2
- IGSF9B | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 106/449 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.069); catalogued as rs371595541; called by muse, mutect2, varscan2
- IL12RB2 | c.2320G>T p.G774C | Missense Mutation (SNP) | VAF 21/602 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV52019893; called by muse, mutect2
- IL2RG | c.1075G>C p.A359P | Missense Mutation (SNP) | VAF 15/427 reads (4%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs1267270801, COSV52148603; called by muse, mutect2
- INTS5 | c.2027G>A p.R676H | Missense Mutation (SNP) | VAF 229/819 reads (28%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.927); catalogued as rs766297241, COSV57953838; called by muse, mutect2, varscan2
- IQCC | c.419C>T p.T140M | Missense Mutation (SNP) | VAF 102/468 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as rs754677770, COSV52208719; called by muse, mutect2, varscan2
- IQCG | c.1228C>T p.R410W | Missense Mutation (SNP) | VAF 207/888 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372501872; called by muse, mutect2, varscan2
- IQCH | c.1955G>A p.R652H | Missense Mutation (SNP) | VAF 124/546 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs769242387, COSV60049680; called by muse, varscan2
- ITGA10 | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 64/266 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782644552; called by muse, mutect2, varscan2
- ITGAL | c.1444G>A p.A482T | Missense Mutation (SNP) | VAF 238/760 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV63323370; called by muse, mutect2, varscan2
- KCNA5 | c.163G>A p.G55S | Missense Mutation (SNP) | VAF 25/285 reads (9%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs958160393; called by muse, mutect2
- KCNJ11 | c.1117G>A p.V373M | Missense Mutation (SNP) | VAF 175/591 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs770375846, COSV60594469; called by muse, mutect2, varscan2
- KCNJ12 | c.601G>A p.V201M | Missense Mutation (SNP) | VAF 168/530 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs147680561; called by muse, mutect2, varscan2
- KCNN3 | c.1697C>T p.A566V (on ENST00000618040 / NM_001204087.1; = p.A551V on NM_002249.6) | Missense Mutation (SNP) | VAF 147/575 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as rs1557944131, COSV55216603; called by muse, mutect2, varscan2
- KCNN3 | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 95/339 reads (28%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.173); catalogued as rs774140951; called by muse, varscan2
- KCNV2 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 65/207 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs369967074; called by muse, mutect2, varscan2
- KDM3B | c.3194G>A p.R1065H | Missense Mutation (SNP) | VAF 395/1059 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.369); catalogued as rs368195001; called by muse, mutect2, varscan2
- KIAA1671 | c.3607G>A p.A1203T | Missense Mutation (SNP) | VAF 116/491 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs1053488098; called by muse, varscan2
- KIF19 | c.1202G>A p.R401H | Missense Mutation (SNP) | VAF 113/357 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs762851827; called by muse, mutect2, varscan2
- KIF24 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 90/394 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); catalogued as rs750485749; called by muse, mutect2, varscan2
- KIF3A | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 66/752 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1368924100, COSV66415195; called by muse, mutect2
- KIF5A | c.217+2T>C p.X73_splice | Splice Site (SNP) | VAF 85/405 reads (21%) | catalogued as COSV54056028; called by muse, mutect2, varscan2
- KMT2D | c.10471C>T p.R3491C | Missense Mutation (SNP) | VAF 191/787 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs902898516, COSV56441923; called by muse, mutect2, varscan2
- KRI1 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 47/429 reads (11%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.735); catalogued as rs201145489; called by muse, mutect2, varscan2
- KRT38 | c.145G>A p.V49M | Missense Mutation (SNP) | VAF 118/284 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as rs749811097, COSV55845227; called by muse, varscan2
- KY | c.862G>A p.G288S | Missense Mutation (SNP) | VAF 120/450 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs368364006; called by muse, varscan2
- L3MBTL2 | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 162/613 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.639); catalogued as rs776241993; called by muse, varscan2
- LAMA1 | c.2700C>T p.R900= | Splice Region (SNP) | VAF 144/562 reads (26%) | catalogued as rs140067215; called by muse, mutect2, varscan2
- LATS2 | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 65/283 reads (23%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.893); catalogued as rs747638434, COSV66875845; called by muse, mutect2, varscan2
- LCT | c.3758C>T p.T1253M | Missense Mutation (SNP) | VAF 142/436 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs772613553, COSV51549287; called by muse, mutect2, varscan2
- LENG8 | c.2240C>T p.T747M (on ENST00000610347 / NM_001375638.1; = p.T747I on NM_052925.4) | Missense Mutation (SNP) | VAF 87/329 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1427031059, COSV100418224; called by muse, mutect2, varscan2
- LPCAT1 | c.1576C>T p.R526W | Missense Mutation (SNP) | VAF 86/822 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as rs140641175; called by muse, varscan2
- LPO | c.1085G>A p.R362H | Missense Mutation (SNP) | VAF 70/494 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as rs771008787, COSV51857909; called by muse, mutect2, varscan2
- LRIF1 | c.1036C>T p.R346* | Nonsense Mutation (SNP) | VAF 172/612 reads (28%) | catalogued as rs375319628; called by muse, varscan2
- LRRC74B | c.1109G>A p.C370Y | Missense Mutation (SNP) | VAF 170/650 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.063); catalogued as COSV61187566; called by muse, mutect2, varscan2
- LRRN4 | c.1298C>T p.T433M | Missense Mutation (SNP) | VAF 120/258 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.68); catalogued as COSV66646337; called by muse, mutect2, varscan2
- LYZL1 | c.556G>A p.E186K (on ENST00000375500; = p.E140K on NM_032517.6) | Missense Mutation (SNP) | VAF 177/738 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs1390744046, COSV64966152; called by muse, mutect2, varscan2
- MAB21L4 | c.1282C>T p.R428W (on ENST00000388934 / NM_001085437.3; = p.R260W on NM_024861.4) | Missense Mutation (SNP) | VAF 120/492 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs769118806, COSV56743132; called by muse, varscan2
- MAP2K4 | c.707T>G p.L236R | Missense Mutation (SNP) | VAF 149/427 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100796564; called by muse, mutect2, varscan2
- MAP3K14 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 121/366 reads (33%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.258); catalogued as rs767596622; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MEX3B | c.1289G>A p.R430H | Missense Mutation (SNP) | VAF 118/454 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.284); catalogued as rs576500562; called by muse, mutect2, varscan2
- MFN2 | c.1556G>A p.R519H | Missense Mutation (SNP) | VAF 176/673 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.731); catalogued as rs373809750, CM115401; ClinVar: uncertain significance; called by muse, varscan2
- MGRN1 | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 146/576 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs747007916; called by muse, varscan2
- MICALL2 | c.2659A>G p.K887E | Missense Mutation (SNP) | VAF 62/430 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as rs1010802336; called by muse, varscan2
- MILR1 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 128/686 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.022); catalogued as rs1244896161; called by muse, mutect2, varscan2
- MLXIPL | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 110/502 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.725); catalogued as rs782082646, COSV57666836; called by muse, mutect2, varscan2
- MMP17 | c.968C>T p.P323L | Missense Mutation (SNP) | VAF 36/339 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs768031584; called by muse, mutect2, varscan2
- MMRN2 | c.1615G>A p.A539T | Missense Mutation (SNP) | VAF 95/296 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs1437528943, COSV100922570; called by muse, varscan2
- MRPS18A | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 190/696 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.962); catalogued as rs542654147; called by muse, varscan2
- MTG2 | c.911G>A p.R304H | Missense Mutation (SNP) | VAF 78/685 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.104); catalogued as rs142898907; called by muse, varscan2
- MUC16 | c.15256C>T p.R5086C | Missense Mutation (SNP) | VAF 134/556 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.265); catalogued as rs751244335, COSV67481460; called by muse, mutect2, varscan2
- MUC5AC | c.1690C>T p.R564C | Missense Mutation (SNP) | VAF 120/410 reads (29%) | SIFT deleterious (0); catalogued as rs776366038; called by muse, mutect2, varscan2
- MUC5AC | c.15586G>A p.A5196T | Missense Mutation (SNP) | VAF 83/331 reads (25%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.962); catalogued as rs926709914; called by muse, mutect2, varscan2
- MYBPH | c.748G>A p.V250M | Missense Mutation (SNP) | VAF 182/780 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as rs139911521; called by muse, mutect2, varscan2
- MYCBPAP | c.1850C>T p.A617V | Missense Mutation (SNP) | VAF 196/736 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100088102; called by muse, mutect2, varscan2
- MYH14 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 16/425 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1005071052, COSV51815545; called by muse, mutect2
- MYH7 | c.1459C>T p.Q487* | Nonsense Mutation (SNP) | VAF 212/1002 reads (21%) | catalogued as COSV100805853; called by muse, varscan2
- MYH7B | c.2513C>T p.A838V | Missense Mutation (SNP) | VAF 222/748 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376063767; called by muse, varscan2
- MYL7 | c.494A>G p.Y165C | Missense Mutation (SNP) | VAF 102/492 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs905789028; called by muse, mutect2, varscan2
- MYO18A | c.275T>C p.L92P | Missense Mutation (SNP) | VAF 26/674 reads (4%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.459); catalogued as COSV62872796; called by muse, mutect2
- NACC2 | c.1312G>T p.A438S | Missense Mutation (SNP) | VAF 24/770 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53200386, COSV53200651; called by muse, mutect2
- NAGLU | c.1516G>A p.G506R | Missense Mutation (SNP) | VAF 44/303 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.739); catalogued as rs1262778017, COSV56794646; called by muse, mutect2, varscan2
- NAPRT | c.567C>T p.G189= | Splice Region (SNP) | VAF 51/231 reads (22%) | catalogued as rs1179007077; called by muse, mutect2, varscan2
- NBEA | c.8267G>A p.R2756Q | Missense Mutation (SNP) | VAF 19/631 reads (3%) | SIFT tolerated (0.2); PolyPhen benign (0.056); catalogued as rs1360065637, COSV59766932; called by muse, mutect2
- NCKIPSD | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 165/727 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.52); catalogued as rs748852507, COSV99584299; called by muse, mutect2, varscan2
- NDUFB7 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 87/290 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.535); catalogued as rs778158600; called by muse, mutect2, varscan2
- NECTIN1 | c.392C>T p.T131M | Missense Mutation (SNP) | VAF 201/757 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as rs377427305; called by muse, mutect2, varscan2
- NECTIN3 | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 44/727 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60550172; called by muse, mutect2
- NEDD9 | c.1961T>C p.M654T | Missense Mutation (SNP) | VAF 69/636 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1164842796; called by muse, varscan2
- NEK10 | c.2318G>A p.R773H | Missense Mutation (SNP) | VAF 234/974 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as rs368785945; called by muse, mutect2, varscan2
- NFX1 | c.2737G>A p.A913T | Missense Mutation (SNP) | VAF 70/802 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.505); catalogued as rs768887823, COSV100780885; called by muse, mutect2
- NHS | c.1504G>A p.A502T | Missense Mutation (SNP) | VAF 184/282 reads (65%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs773561656; called by muse, mutect2, varscan2
- NID1 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 84/295 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs1385641766; called by muse, mutect2, varscan2
- NPRL3 | c.1607G>A p.R536Q (on ENST00000611875 / NM_001077350.3; = p.R511Q on NM_001039476.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 219/642 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs759994243, COSV99549936; called by muse, mutect2, varscan2
- NR5A1 | c.1093C>T p.R365W | Missense Mutation (SNP) | VAF 132/432 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs1564149534; called by muse, mutect2, varscan2
- NSMF | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 55/226 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.394); catalogued as rs767664655; called by muse, mutect2, varscan2
- NTM | c.529G>A p.V177I | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.425); catalogued as COSV66177987; called by muse, mutect2, varscan2
- NUP133 | c.3335-1G>T p.X1112_splice | Splice Site (SNP) | VAF 22/355 reads (6%) | catalogued as COSV54571841; called by muse, mutect2
- NUP188 | c.4285C>T p.R1429W | Missense Mutation (SNP) | VAF 186/761 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1159694158; called by muse, mutect2, varscan2
- OBSCN | c.21088C>T p.Q7030* | Nonsense Mutation (SNP) | VAF 66/273 reads (24%) | catalogued as rs1410967667; called by muse, mutect2, varscan2
- OR1M1 | c.370G>A p.V124M | Missense Mutation (SNP) | VAF 44/231 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs148262558; called by muse, mutect2, varscan2
- OR2G6 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 149/581 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0.015); catalogued as rs375204402, COSV58573740; called by muse, mutect2, varscan2
- OR4P4 | c.854A>G p.Y285C | Missense Mutation (SNP) | VAF 197/794 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.32); catalogued as rs1169311118; called by muse, varscan2
- OR51B2 | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 83/586 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as rs770237512, COSV60917092; called by muse, mutect2, varscan2
- OR5AU1 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 87/257 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); catalogued as rs771542595; called by muse, mutect2, varscan2
- OS9 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 174/738 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as rs758479931; called by muse, mutect2, varscan2
- OSBPL5 | c.892G>A p.D298N | Missense Mutation (SNP) | VAF 183/684 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs745480803; called by muse, mutect2, varscan2
- PACSIN3 | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 129/517 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as rs774976753; called by muse, mutect2, varscan2
- PADI1 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 133/503 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs371358492; called by muse, mutect2, varscan2
- PAQR6 | c.296G>A p.C99Y | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs778266865; called by muse, varscan2
- PARD3B | c.512C>T p.T171M | Missense Mutation (SNP) | VAF 75/345 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs374453548; called by muse, varscan2
- PATJ | c.901G>A p.V301M | Missense Mutation (SNP) | VAF 137/528 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs1472357067, COSV57159389; called by muse, mutect2, varscan2
- PBXIP1 | c.1262G>A p.R421H | Missense Mutation (SNP) | VAF 48/178 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs748232786; called by muse, varscan2
- PCDHA10 | c.1903G>A p.A635T | Missense Mutation (SNP) | VAF 256/930 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.087); catalogued as rs569786768, COSV100247819; called by muse, mutect2
- PCDHA13 | c.1505G>A p.R502H | Missense Mutation (SNP) | VAF 139/339 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.421); catalogued as COSV56497645; called by muse, mutect2, varscan2
- PCDHA8 | c.1745C>T p.P582L | Missense Mutation (SNP) | VAF 232/630 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.036); catalogued as rs782077054, COSV65327429; called by muse, mutect2
- PCDHGA6 | c.2017G>A p.A673T | Missense Mutation (SNP) | VAF 57/298 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.033); catalogued as rs772318189; called by muse, mutect2, varscan2
- PCYOX1L | c.1355C>T p.A452V | Missense Mutation (SNP) | VAF 330/910 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.103); catalogued as rs1332570503, COSV99199190; called by muse, varscan2
- PDE6B | c.2030C>T p.A677V | Missense Mutation (SNP) | VAF 246/844 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as rs756335597, COSV55326125; called by muse, varscan2
- PDZD2 | c.6253G>A p.E2085K | Missense Mutation (SNP) | VAF 93/364 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as rs140544837, COSV56877987; called by muse, varscan2
- PHACTR3 | c.134C>T p.T45M | Missense Mutation (SNP) | VAF 138/588 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.183); catalogued as rs144421959; called by muse, mutect2, varscan2
- PHLDB1 | c.3332C>T p.T1111M | Missense Mutation (SNP) | VAF 69/323 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781807711; called by muse, varscan2
- PIPOX | c.157C>T p.R53W | Missense Mutation (SNP) | VAF 209/909 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs543013733; called by muse, mutect2, varscan2
- PKD1 | c.9469G>A p.D3157N | Missense Mutation (SNP) | VAF 111/505 reads (22%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.857); catalogued as rs779683697; called by muse, mutect2, varscan2
- PKHD1 | c.3943C>A p.L1315M | Missense Mutation (SNP) | VAF 41/320 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.344); catalogued as COSV61866245; called by muse, mutect2, varscan2
- PLEKHA6 | c.1799G>A p.R600H | Missense Mutation (SNP) | VAF 123/571 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.934); catalogued as rs769462449, COSV55330371, COSV55331485; called by muse, mutect2, varscan2
- PLEKHM2 | c.2731C>T p.R911C | Missense Mutation (SNP) | VAF 189/741 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1316562875; called by muse, mutect2, varscan2
- PLK1 | c.1736G>A p.R579Q | Missense Mutation (SNP) | VAF 29/678 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs984791278, COSV55621213; called by muse, mutect2
- PLXNB1 | c.3149G>A p.R1050H | Missense Mutation (SNP) | VAF 126/413 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs759260268, COSV56488633; called by muse, mutect2, varscan2
- PLXNB3 | c.3166G>A p.A1056T | Missense Mutation (SNP) | VAF 58/176 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.014); catalogued as rs782450733; called by muse, mutect2, varscan2
- PML | c.2263C>T p.R755C | Missense Mutation (SNP) | VAF 84/335 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs756651718; called by muse, mutect2, varscan2
- PNKP | c.1327G>A p.V443I | Missense Mutation (SNP) | VAF 105/403 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as rs1421167718; called by muse, mutect2, varscan2
- POC1B | c.810G>A p.T270= | Splice Region (SNP) | VAF 76/302 reads (25%) | catalogued as rs748734060, COSV100544143; called by muse, mutect2, varscan2
- PODNL1 | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 42/213 reads (20%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.017); catalogued as rs776936134, COSV54309376; called by muse, mutect2, varscan2
- PPL | c.1362dup p.T455Hfs*4 | Frame Shift Ins (INS) | VAF 154/398 reads (39%) | catalogued as rs753902804; called by mutect2, varscan2
- PPP3CB | c.1414C>A p.P472T | Missense Mutation (SNP) | VAF 106/458 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); catalogued as COSV55018753; called by muse, varscan2
- PRIMPOL | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 115/513 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as rs374000795; called by muse, mutect2, varscan2
- PRKDC | c.1714G>A p.V572I | Missense Mutation (SNP) | VAF 87/462 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0.015); catalogued as rs1184535587, COSV58049694; called by muse, mutect2, varscan2
- PRX | c.1469G>A p.R490Q | Missense Mutation (SNP) | VAF 180/730 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.284); catalogued as rs752314625, COSV52527306; called by muse, mutect2, varscan2
- PTPRN2 | c.2305G>A p.E769K | Missense Mutation (SNP) | VAF 122/493 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.053); catalogued as COSV67035591; called by muse, varscan2
- PXDN | c.3385C>T p.R1129C | Missense Mutation (SNP) | VAF 54/768 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs375850501; called by muse, mutect2
- PXDN | c.1423G>A p.V475M | Missense Mutation (SNP) | VAF 125/486 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.781); catalogued as rs772534828, COSV53235772; called by muse, mutect2, varscan2
- RAD9A | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 116/506 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762431269, COSV57236955; called by muse, mutect2, varscan2
- RASGRF2 | c.2578C>T p.R860C | Missense Mutation (SNP) | VAF 199/693 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); catalogued as rs767446101, COSV54128278; called by muse, mutect2, varscan2
- RBMXL3 | c.1066G>A p.A356T | Missense Mutation (SNP) | VAF 108/354 reads (31%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.821); catalogued as rs868939125, COSV57760835; called by muse, mutect2, varscan2
- REG3A | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 212/989 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as rs1370503388, COSV59408953; called by muse, mutect2, varscan2
- RFC3 | c.244del p.I82Lfs*25 | Frame Shift Del (DEL) | VAF 60/244 reads (25%) | catalogued as rs753959887; called by mutect2, varscan2
- RHOXF2 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 35/794 reads (4%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.829); catalogued as rs1309289784; called by muse, mutect2
- RMND5B | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 343/943 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as rs376722623; called by muse, mutect2, varscan2
- RNF103 | c.1988G>A p.R663Q | Missense Mutation (SNP) | VAF 142/593 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs1403005290, COSV52897849; called by muse, varscan2
- RNF148 | c.440C>T p.T147M | Missense Mutation (SNP) | VAF 141/633 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.922); catalogued as rs201973741; called by muse, mutect2, varscan2
- RNF207 | c.1105A>G p.N369D | Missense Mutation (SNP) | VAF 106/373 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.026); catalogued as rs1557587929; called by muse, mutect2, varscan2
- RNF222 | c.17G>T p.S6I | Missense Mutation (SNP) | VAF 111/286 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as rs1264678804; called by muse, mutect2, varscan2
- ROBO1 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 60/688 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.982); catalogued as rs377370843, COSV71398893; called by muse, mutect2
- ROR2 | c.703G>A p.V235M | Missense Mutation (SNP) | VAF 136/556 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs140179632; called by muse, varscan2
- RPH3A | c.1846G>A p.E616K (on ENST00000389385 / NM_001143854.2; = p.E612K on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 88/752 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1410288764, COSV66989937; called by muse, mutect2, varscan2
- RPP25L | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 42/714 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.011); catalogued as COSV52408860; called by muse, mutect2
- RPS6KA4 | c.2141G>A p.R714Q | Missense Mutation (SNP) | VAF 116/492 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as rs901715491; called by muse, varscan2
- RRP1 | c.883G>A p.V295I | Missense Mutation (SNP) | VAF 119/459 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as rs769697557; called by muse, mutect2
- RTF1 | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 233/851 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1318152324; called by muse, mutect2, varscan2
- RUNX3 | c.1120G>A p.G374S | Missense Mutation (SNP) | VAF 58/197 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs777246232; called by muse, mutect2, varscan2
- SALL4 | c.1349C>T p.A450V | Missense Mutation (SNP) | VAF 162/522 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs760849620, COSV53850660; called by muse, varscan2
- SCNN1B | c.515A>G p.N172S | Missense Mutation (SNP) | VAF 162/912 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs748642280; called by muse, mutect2, varscan2
- SCP2 | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 107/788 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV101027292; called by muse, mutect2, varscan2
- SCP2 | c.1166A>G p.Q389R | Missense Mutation (SNP) | VAF 143/654 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV65261225; called by muse, mutect2, varscan2
- SEBOX | c.553G>A p.V185I | Missense Mutation (SNP) | VAF 133/510 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs199744922; called by muse, mutect2, varscan2
- SEC16A | c.2312G>A p.R771Q | Missense Mutation (SNP) | VAF 166/592 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as rs374699588; called by muse, varscan2
- SEC24A | c.2636G>A p.R879H | Missense Mutation (SNP) | VAF 358/1023 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs777619862, COSV67305069; called by muse, varscan2
- SETD1B | c.2861G>A p.R954H | Missense Mutation (SNP) | VAF 60/232 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.882); catalogued as rs367913171; called by muse, mutect2, varscan2
- SF1 | c.1234C>T p.P412S | Missense Mutation (SNP) | VAF 96/311 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); catalogued as COSV57116438; called by muse, mutect2, varscan2
- SFMBT1 | c.1370G>A p.R457Q | Missense Mutation (SNP) | VAF 120/462 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.226); catalogued as rs752497833; called by muse, varscan2
- SHANK2 | c.3241G>A p.A1081T | Missense Mutation (SNP) | VAF 50/403 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1181466605, COSV99572354; called by muse, mutect2, varscan2
- SHROOM1 | c.2534C>T p.P845L (on ENST00000378679 / NM_001172700.2; = p.P840L on NM_133456.2) | Missense Mutation (SNP) | VAF 230/669 reads (34%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.437); catalogued as rs1454979486; called by muse, mutect2, varscan2
- SHROOM4 | c.1226G>A p.R409H | Missense Mutation (SNP) | VAF 40/327 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as rs371697426, COSV56784797; called by muse, mutect2, varscan2
- SHTN1 | c.1445G>A p.R482H | Missense Mutation (SNP) | VAF 209/863 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs764643872; called by muse, mutect2, varscan2
- SIRT6 | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as rs992892719, COSV50176742; called by muse, mutect2
- SLC22A12 | c.425A>G p.H142R | Missense Mutation (SNP) | VAF 32/956 reads (3%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as rs994709541; called by muse, mutect2
- SLC25A36 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 147/459 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs376063048; called by muse, mutect2, varscan2
- SLC25A6 | c.307G>A p.V103M | Missense Mutation (SNP) | VAF 119/553 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as rs764365091; called by muse, mutect2, varscan2
- SLC30A3 | c.244G>A p.V82I | Missense Mutation (SNP) | VAF 176/614 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.131); catalogued as rs749270034, COSV51986908; called by muse, mutect2, varscan2
- SLC41A1 | c.1408C>T p.R470W | Missense Mutation (SNP) | VAF 172/594 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as rs144675068, COSV65651814; called by muse, mutect2, varscan2
- SLC43A1 | c.1607G>A p.R536Q | Missense Mutation (SNP) | VAF 205/852 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs376876605; called by muse, varscan2
- SLC7A10 | c.1108G>A p.V370I | Missense Mutation (SNP) | VAF 90/348 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs747259328; called by muse, varscan2
- SLC8A2 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 68/454 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as COSV52637968; called by muse, mutect2, varscan2
- SLC9A3 | c.1486G>A p.G496R | Missense Mutation (SNP) | VAF 203/648 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377525383; called by muse, mutect2, varscan2
- SLX4 | c.3311G>A p.R1104Q | Missense Mutation (SNP) | VAF 218/574 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs767093188; called by muse, mutect2, varscan2
- SMURF2 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 157/495 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as COSV52312522; called by muse, mutect2, varscan2
- SNAPC4 | c.3359G>A p.R1120Q | Missense Mutation (SNP) | VAF 117/396 reads (30%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs539899505; called by muse, mutect2, varscan2
- SOX17 | c.899T>C p.M300T | Missense Mutation (SNP) | VAF 73/271 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.091); catalogued as COSV52027910; called by muse, mutect2, varscan2
- SPEG | c.3918del p.R1307Gfs*12 | Frame Shift Del (DEL) | VAF 50/418 reads (12%) | catalogued as rs771765677; called by mutect2, varscan2
- SPEG | c.5089C>T p.R1697W | Missense Mutation (SNP) | VAF 86/439 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100403427; called by muse, mutect2, varscan2
- SPIRE2 | c.599C>T p.T200M | Missense Mutation (SNP) | VAF 266/577 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1179473598; called by muse, varscan2
- SPON1 | c.1742G>A p.R581Q | Missense Mutation (SNP) | VAF 85/385 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1352595888; called by muse, mutect2, varscan2
- SPRED1 | c.1006G>A p.V336I | Missense Mutation (SNP) | VAF 179/680 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0.03); catalogued as rs373477920; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPTBN1 | c.2405C>T p.T802M | Missense Mutation (SNP) | VAF 223/833 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.532); catalogued as rs756652288; called by muse, mutect2, varscan2
- SPTBN4 | c.7685G>A p.R2562H | Missense Mutation (SNP) | VAF 123/420 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.707); catalogued as rs765129909, COSV99398849; called by muse, mutect2, varscan2
- SRSF6 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 249/992 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs148216368; called by muse, mutect2, varscan2
- SSX1 | c.41A>G p.D14G | Missense Mutation (SNP) | VAF 25/761 reads (3%) | SIFT tolerated (0.47); PolyPhen benign (0.034); catalogued as COSV65354972; called by muse, mutect2
- STAB2 | c.6136G>T p.V2046F | Missense Mutation (SNP) | VAF 43/474 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as rs1189665844, COSV66334187; called by muse, mutect2
- STEAP3 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 131/525 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs747929489; called by muse, mutect2, varscan2
- STIM1 | c.1672C>T p.R558W | Missense Mutation (SNP) | VAF 99/564 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.649); catalogued as rs747547917; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- STYXL2 | c.1750G>A p.V584I | Missense Mutation (SNP) | VAF 122/477 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs369939829, COSV54808365; called by muse, mutect2, varscan2
- SUGP1 | c.1642C>T p.R548C | Missense Mutation (SNP) | VAF 87/392 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs751111630, COSV99895019; called by muse, mutect2, varscan2
- SUPT5H | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 143/575 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63238497; called by muse, varscan2
- SUPT5H | c.3160G>A p.V1054I | Missense Mutation (SNP) | VAF 96/373 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs577692870; called by muse, mutect2, varscan2
- SYDE1 | c.1640G>A p.R547H | Missense Mutation (SNP) | VAF 117/508 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs777925844; called by muse, mutect2, varscan2
- SYNJ2 | c.2002G>A p.V668I | Missense Mutation (SNP) | VAF 99/404 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs755941692; called by muse, mutect2, varscan2
- SYS1 | c.373G>A p.V125M | Missense Mutation (SNP) | VAF 63/591 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.721); catalogued as rs1007673140, COSV54781621; called by muse, mutect2, varscan2
- SYT5 | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 198/826 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as rs1178099622; called by muse, mutect2, varscan2
- TAB1 | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 124/350 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as rs781515810, COSV53372153; called by muse, mutect2, varscan2
- TAS2R50 | c.506G>T p.R169M | Missense Mutation (SNP) | VAF 84/400 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.209); catalogued as COSV101115715, COSV67853340; called by mutect2, varscan2
- TCP10L2 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 132/827 reads (16%) | SIFT tolerated (1); PolyPhen probably damaging (0.931); catalogued as rs1221079621; called by muse, mutect2
- TDRD9 | c.1496G>A p.R499Q | Missense Mutation (SNP) | VAF 50/276 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773721878; called by muse, varscan2
- TECTA | c.4144G>A p.V1382M | Missense Mutation (SNP) | VAF 183/675 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.119); catalogued as rs199637730, COSV50689122; called by muse, mutect2, varscan2
- TEX13A | c.182G>T p.S61I | Missense Mutation (SNP) | VAF 67/404 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); catalogued as COSV100781265; called by muse, mutect2, varscan2
- TFE3 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 44/409 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1557075151; called by muse, mutect2, varscan2
- TGFB1I1 | c.715-4G>A | Splice Region (SNP) | VAF 99/518 reads (19%) | catalogued as rs200494014; called by muse, mutect2, varscan2
- THSD7B | c.2102G>A p.R701Q | Missense Mutation (SNP) | VAF 160/639 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1419170612; called by muse, mutect2, varscan2
- TICRR | c.5432C>T p.A1811V | Missense Mutation (SNP) | VAF 64/344 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs769022345; called by muse, varscan2
- TIGD5 | c.694G>A p.G232R | Missense Mutation (SNP) | VAF 7/164 reads (4%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.912); catalogued as rs1383201430; called by muse, mutect2
- TJP3 | c.1769G>A p.R590Q | Missense Mutation (SNP) | VAF 95/335 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.04); catalogued as rs771343292; called by muse, mutect2, varscan2
- TLE3 | c.1664C>T p.T555M | Missense Mutation (SNP) | VAF 29/415 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1400487362; called by muse, mutect2
- TMEM151A | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 93/381 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as rs1245729165; called by muse, mutect2, varscan2
- TMEM43 | c.1177C>T p.R393W | Missense Mutation (SNP) | VAF 155/694 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs765762863; ClinVar: uncertain significance; called by muse, varscan2
- TNFRSF25 | c.1243C>T p.R415C | Missense Mutation (SNP) | VAF 90/371 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as rs749965999; called by muse, varscan2
- TNP2 | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 282/750 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs750517920, COSV57129406; called by muse, mutect2, varscan2
- TNXB | c.5698C>T p.R1900* (on ENST00000647633; = p.R1653* on NM_019105.8 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 208/585 reads (36%) | catalogued as rs201184519, COSV100926523; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TNXB | c.2357C>T p.T786M | Missense Mutation (SNP) | VAF 143/448 reads (32%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.454); catalogued as rs759186959, COSV100926473; called by muse, varscan2
- TOR1AIP2 | c.292G>A p.G98R | Missense Mutation (SNP) | VAF 141/500 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.028); catalogued as rs772856426, COSV100857265, COSV100857437; called by muse, mutect2, varscan2
- TRAIP | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 221/866 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs866810011, COSV58917462; called by muse, mutect2, varscan2
- TRIM3 | c.1249C>T p.R417C | Missense Mutation (SNP) | VAF 120/430 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs775151876, COSV61983955; called by muse, varscan2
- TRIM3 | c.1087C>T p.R363C | Missense Mutation (SNP) | VAF 53/546 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs1430167726; called by muse, mutect2
- TRIM41 | c.694G>T p.E232* | Nonsense Mutation (SNP) | VAF 314/1099 reads (29%) | catalogued as COSV59317827; called by muse, mutect2, varscan2
- TRIM51 | c.430del p.M144Cfs*15 | Frame Shift Del (DEL) | VAF 182/714 reads (25%) | catalogued as rs763121810; called by mutect2, varscan2
- TRRAP | c.7570G>A p.V2524I (on ENST00000359863 / NM_001244580.1; = p.V2506I on NM_003496.3) | Missense Mutation (SNP) | VAF 36/768 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.044); catalogued as rs1331659399; called by muse, mutect2
- TSPAN33 | c.142C>T p.R48W | Missense Mutation (SNP) | VAF 109/465 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs773935556, COSV56826978; called by muse, mutect2, varscan2
- UBLCP1 | c.833G>A p.R278H | Missense Mutation (SNP) | VAF 104/532 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as rs767226231; called by muse, mutect2, varscan2
- UFSP2 | c.392C>T p.T131M | Missense Mutation (SNP) | VAF 98/492 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as rs777270795, COSV99248826; called by muse, mutect2, varscan2
- USP7 | c.1927G>A p.D643N | Missense Mutation (SNP) | VAF 46/813 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs761125187, COSV61212834; called by muse, mutect2
- VEGFC | c.1157G>A p.R386Q | Missense Mutation (SNP) | VAF 108/575 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.198); catalogued as rs368084817; called by muse, mutect2, varscan2
- WNT9B | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 219/742 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs775970973; called by muse, mutect2
- YTHDC1 | c.1264G>A p.G422R (on ENST00000344157 / NM_001031732.4; = p.G404R on NM_133370.4) | Missense Mutation (SNP) | VAF 132/494 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as rs778939077; called by muse, mutect2, varscan2
- ZC3H7A | c.2138C>A p.A713D | Missense Mutation (SNP) | VAF 101/683 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV63271604; called by muse, mutect2, varscan2
- ZMIZ1 | c.1055C>T p.A352V | Missense Mutation (SNP) | VAF 90/324 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.011); catalogued as rs201265689; called by muse, mutect2, varscan2
- ZMIZ1 | c.1388C>T p.T463M | Missense Mutation (SNP) | VAF 121/433 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.513); catalogued as rs781519303, COSV57894136; called by muse, mutect2, varscan2
- ZNF236 | c.2095G>A p.V699M | Missense Mutation (SNP) | VAF 202/688 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1470175148, COSV53486142; called by muse, mutect2, varscan2
- ZNF469 | c.9367C>T p.R3123C (on ENST00000437464; = p.R3151C on NM_001367624.2) | Missense Mutation (SNP) | VAF 280/720 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755567767; called by muse, mutect2, varscan2
- ZNF540 | c.445del p.M149Cfs*12 | Frame Shift Del (DEL) | VAF 81/349 reads (23%) | catalogued as COSV100329754, COSV57108094; called by mutect2, varscan2
- ZNF569 | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 16/443 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.207); catalogued as COSV57594718; called by muse, mutect2
- ZNF579 | c.895G>A p.V299M | Missense Mutation (SNP) | VAF 99/389 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.806); catalogued as COSV57638751; called by muse, mutect2, varscan2
- ZNF672 | c.646C>T p.R216* | Nonsense Mutation (SNP) | VAF 53/725 reads (7%) | catalogued as rs1472145246; called by muse, mutect2
- ZNF688 | c.349G>T p.V117F | Missense Mutation (SNP) | VAF 108/492 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.025); catalogued as rs754234250; called by muse, mutect2, varscan2
- ZNF707 | c.764C>T p.T255I | Missense Mutation (SNP) | VAF 35/462 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs781882112; called by muse, mutect2
- ZNF740 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 72/613 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV57237682; called by muse, mutect2, varscan2
- ZNF879 | c.1411G>A p.V471I | Missense Mutation (SNP) | VAF 208/561 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as rs753251132, COSV71423762; called by muse, varscan2
- ZP2 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 84/511 reads (16%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.397); catalogued as rs573749216; called by muse, mutect2, varscan2
- ZSWIM5 | c.1828G>A p.D610N | Missense Mutation (SNP) | VAF 238/840 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs747633214; called by muse, mutect2, varscan2
- ABCF2 | c.1689G>T p.E563D | Missense Mutation (SNP) | VAF 144/664 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, varscan2
- ACLY | c.3095C>T p.A1032V | Missense Mutation (SNP) | VAF 125/593 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- ADAM23 | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 21/789 reads (3%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.602); called by muse, mutect2
- ADAMTS14 | c.688C>A p.L230M | Missense Mutation (SNP) | VAF 58/770 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.713); called by muse, mutect2
- ADAMTS6 | c.2884C>T p.Q962* | Nonsense Mutation (SNP) | VAF 176/730 reads (24%) | called by muse, mutect2, varscan2
- ADCY3 | c.2545A>G p.M849V | Missense Mutation (SNP) | VAF 151/616 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRE5 | c.1955C>T p.T652M (on ENST00000242786 / NM_078481.4; = p.T559M on NM_001784.5) | Missense Mutation (SNP) | VAF 124/472 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- ADGRL4 | c.1097A>G p.Y366C | Missense Mutation (SNP) | VAF 102/384 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- AFF3 | c.580C>T p.Q194* | Nonsense Mutation (SNP) | VAF 46/754 reads (6%) | called by muse, mutect2
- AGRN | c.758G>A p.C253Y | Missense Mutation (SNP) | VAF 41/291 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ALDH3B1 | c.632T>G p.L211R | Missense Mutation (SNP) | VAF 100/419 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANO7 | c.1489A>G p.M497V (on ENST00000274979; = p.M443V on NM_001370694.2) | Missense Mutation (SNP) | VAF 22/480 reads (5%) | SIFT tolerated (0.84); PolyPhen benign (0.001); called by muse, mutect2
- ARHGEF10L | c.3064G>A p.A1022T | Missense Mutation (SNP) | VAF 131/422 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASMT | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 26/611 reads (4%) | called by muse, mutect2
- ATP11B | c.2785A>G p.S929G | Missense Mutation (SNP) | VAF 163/557 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ATXN2 | c.2986A>G p.T996A (on ENST00000550104; = p.T836A on NM_002973.4) | Missense Mutation (SNP) | VAF 204/891 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- BCAR1 | c.2323C>T p.P775S | Missense Mutation (SNP) | VAF 160/443 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- BCO1 | c.324-1G>T p.X108_splice | Splice Site (SNP) | VAF 299/753 reads (40%) | called by muse, mutect2, varscan2
- BICDL2 | c.775C>T p.R259W | Missense Mutation (SNP) | VAF 74/362 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- BNIP5 | c.1829A>C p.K610T | Missense Mutation (SNP) | VAF 122/628 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- BRDT | c.1253A>T p.E418V | Missense Mutation (SNP) | VAF 190/615 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- C2CD2 | c.887T>A p.V296D | Missense Mutation (SNP) | VAF 72/1038 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.129); called by muse, mutect2
- C2orf92 | c.743dup p.N248Kfs*89 | Frame Shift Ins (INS) | VAF 103/704 reads (15%) | called by mutect2, varscan2
- C4A | c.2699C>A p.S900Y | Missense Mutation (SNP) | VAF 102/1212 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); called by muse, mutect2
- C5orf22 | c.253A>G p.M85V | Missense Mutation (SNP) | VAF 33/675 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.11); called by muse, mutect2
- C9orf92 | n.209C>T | Splice Region (SNP) | VAF 75/306 reads (25%) | called by muse, mutect2, varscan2
- CACNA1I | c.6567del p.G2190Afs*82 | Frame Shift Del (DEL) | VAF 82/217 reads (38%) | called by mutect2, varscan2
- CACNA2D3 | c.2804T>C p.M935T | Missense Mutation (SNP) | VAF 126/590 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CARD11 | c.3458A>G p.Q1153R | Missense Mutation (SNP) | VAF 79/555 reads (14%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCDC39 | c.2267G>T p.S756I | Missense Mutation (SNP) | VAF 18/193 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.234); called by muse, mutect2
- CCDC85A | c.570G>T p.Q190H | Missense Mutation (SNP) | VAF 41/199 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- CCNB3 | c.3593G>A p.C1198Y | Missense Mutation (SNP) | VAF 405/609 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CCNC | c.140-7C>A | Splice Region (SNP) | VAF 52/321 reads (16%) | called by muse, mutect2, varscan2
- CCT8 | c.738dup p.D247* | Frame Shift Ins (INS) | VAF 96/688 reads (14%) | called by mutect2, varscan2
- CDADC1 | c.577C>T p.Q193* | Nonsense Mutation (SNP) | VAF 99/704 reads (14%) | called by muse, mutect2, varscan2
- CDH2 | c.707G>T p.R236M | Missense Mutation (SNP) | VAF 27/446 reads (6%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.898); called by muse, mutect2
- CFAP100 | c.899C>T p.T300I | Missense Mutation (SNP) | VAF 125/534 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFAP47 | c.9206C>T p.A3069V | Missense Mutation (SNP) | VAF 117/398 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CFAP92 | c.-32-4C>T | Splice Region (SNP) | VAF 20/83 reads (24%) | called by muse, mutect2, varscan2
- CHST8 | c.1058A>G p.D353G | Missense Mutation (SNP) | VAF 107/405 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- CHSY3 | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 25/312 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); called by muse, mutect2
- CLK3 | c.685G>T p.E229* (on ENST00000395066 / NM_001130028.1; = p.E81* on NM_003992.4) | Nonsense Mutation (SNP) | VAF 57/373 reads (15%) | called by muse, mutect2, varscan2
- CNOT11 | c.329T>C p.M110T | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- COL4A5 | c.3374-1G>A p.X1125_splice | Splice Site (SNP) | VAF 294/461 reads (64%) | called by muse, mutect2, varscan2
- COL6A5 | c.7484T>C p.I2495T (on ENST00000312481; = p.I2491T on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 81/286 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- COQ8B | c.131del p.K44Sfs*32 | Frame Shift Del (DEL) | VAF 192/706 reads (27%) | called by mutect2, varscan2
- CPNE9 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 82/447 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.351); called by muse, varscan2
- CPSF1 | c.4133C>A p.P1378H | Missense Mutation (SNP) | VAF 51/276 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CROCC | c.3613C>A p.L1205M | Missense Mutation (SNP) | VAF 46/468 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2
- CRTAC1 | c.1204G>T p.G402C | Missense Mutation (SNP) | VAF 22/528 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CRYM | c.647G>T p.W216L | Missense Mutation (SNP) | VAF 115/627 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- DAB2IP | c.2668G>A p.A890T (on ENST00000408936; = p.A862T on NM_032552.3) | Missense Mutation (SNP) | VAF 20/362 reads (6%) | SIFT tolerated (0.89); PolyPhen benign (0.012); called by muse, mutect2
- DDX19B | c.256T>C p.S86P | Missense Mutation (SNP) | VAF 26/948 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2
- DNAH5 | c.11274G>T p.K3758N | Missense Mutation (SNP) | VAF 234/907 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- DNAJC1 | c.1219C>T p.P407S | Missense Mutation (SNP) | VAF 281/1120 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DOCK10 | c.2554A>G p.T852A | Missense Mutation (SNP) | VAF 71/370 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DUS1L | c.701G>A p.G234D | Missense Mutation (SNP) | VAF 136/826 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- DVL3 | c.174G>T p.E58D | Missense Mutation (SNP) | VAF 38/462 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- EDEM1 | c.1507C>A p.Q503K | Missense Mutation (SNP) | VAF 115/487 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- EEF1AKMT2 | c.400-3T>C | Splice Region (SNP) | VAF 112/437 reads (26%) | called by muse, varscan2
- EEF1AKNMT | c.2044G>A p.G682S (on ENST00000361735 / NM_015935.5; = p.G596S on NM_014955.3) | Missense Mutation (SNP) | VAF 31/723 reads (4%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2
- EFCAB12 | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 184/589 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- EFR3B | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 116/532 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.007); called by muse, varscan2
- EIF2AK3 | c.778A>G p.S260G | Missense Mutation (SNP) | VAF 130/450 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ENPP7 | c.254-2A>G p.X85_splice | Splice Site (SNP) | VAF 165/726 reads (23%) | called by muse, varscan2
- ENTPD7 | c.274A>G p.S92G | Missense Mutation (SNP) | VAF 31/942 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ERC1 | c.2818G>A p.A940T (on ENST00000360905 / NM_178040.4; = p.A912T on NM_178039.4) | Missense Mutation (SNP) | VAF 159/817 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EYS | c.1243C>T p.L415F | Missense Mutation (SNP) | VAF 85/343 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- F2R | c.1183A>G p.S395G | Missense Mutation (SNP) | VAF 280/799 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM117A | c.947G>C p.G316A | Missense Mutation (SNP) | VAF 158/894 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.04); called by muse, varscan2
- FAM186A | c.3008T>C p.I1003T | Missense Mutation (SNP) | VAF 166/608 reads (27%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, varscan2
- FAM193B | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 52/736 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.01); called by muse, mutect2
- FAP | c.2219C>T p.S740F | Missense Mutation (SNP) | VAF 70/957 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- FAT1 | c.12749C>A p.P4250H | Missense Mutation (SNP) | VAF 145/486 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAT1 | c.12643G>A p.E4215K | Missense Mutation (SNP) | VAF 137/453 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- FAT1 | c.8758G>A p.A2920T | Missense Mutation (SNP) | VAF 18/440 reads (4%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.962); called by muse, mutect2
- FBXO40 | c.1888G>T p.G630C | Missense Mutation (SNP) | VAF 135/544 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- FEM1A | c.750G>T p.Q250H | Missense Mutation (SNP) | VAF 62/333 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- FGF13 | c.68del p.P23Lfs*19 | Frame Shift Del (DEL) | VAF 114/384 reads (30%) | called by mutect2, varscan2
- FGF3 | c.29G>A p.S10N | Missense Mutation (SNP) | VAF 61/196 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FHAD1 | c.2207G>T p.R736I | Missense Mutation (SNP) | VAF 149/1062 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- FLNA | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 154/470 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- FOXB1 | c.812C>A p.P271H | Missense Mutation (SNP) | VAF 22/291 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.575); called by muse, mutect2
- FOXC2 | c.1252G>A p.A418T | Missense Mutation (SNP) | VAF 81/337 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- FOXRED2 | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 71/267 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- FRMPD3 | c.4448A>G p.D1483G | Missense Mutation (SNP) | VAF 42/196 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- GABRR3 | c.334C>T p.H112Y | Missense Mutation (SNP) | VAF 146/712 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, varscan2
- GAP43 | c.667C>T p.Q223* | Nonsense Mutation (SNP) | VAF 124/614 reads (20%) | called by muse, mutect2, varscan2
- GBP1 | c.1330A>G p.K444E | Missense Mutation (SNP) | VAF 35/679 reads (5%) | SIFT tolerated (0.81); PolyPhen benign (0.04); called by muse, mutect2
- GCGR | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 21/643 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); called by muse, mutect2
- GFRA3 | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 39/920 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); called by muse, mutect2
- GLUD1 | c.1557+1G>A p.X519_splice | Splice Site (SNP) | VAF 91/637 reads (14%) | called by muse, mutect2, varscan2
- GPAA1 | c.436C>T p.L146F | Missense Mutation (SNP) | VAF 88/512 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- GPBAR1 | c.629A>G p.E210G | Missense Mutation (SNP) | VAF 123/443 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GPR158 | c.2870C>T p.A957V | Missense Mutation (SNP) | VAF 118/476 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR61 | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 142/511 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- HIRIP3 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 230/561 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HK1 | c.2447G>T p.S816I | Missense Mutation (SNP) | VAF 177/712 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- HMCN1 | c.1305G>A p.M435I | Missense Mutation (SNP) | VAF 111/477 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- HMCN2 | c.3484+1G>A p.X1162_splice | Splice Site (SNP) | VAF 18/219 reads (8%) | called by muse, mutect2
- HMG20B | c.723G>T p.E241D | Missense Mutation (SNP) | VAF 39/170 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- HNRNPUL2 | c.2236T>C p.Y746H | Missense Mutation (SNP) | VAF 59/656 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.829); called by muse, mutect2
- HROB | c.289G>T p.G97* | Nonsense Mutation (SNP) | VAF 78/1130 reads (7%) | called by muse, mutect2
- IL1RAPL1 | c.1898C>A p.P633H | Missense Mutation (SNP) | VAF 238/366 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.717); called by muse, varscan2
- IL20RB | c.936G>T p.*312Yext*15 | Nonstop Mutation (SNP) | VAF 23/566 reads (4%) | called by muse, mutect2
- IP6K1 | c.1303C>T p.Q435* | Nonsense Mutation (SNP) | VAF 18/510 reads (4%) | called by muse, mutect2
- ITGB7 | c.1561C>A p.P521T | Missense Mutation (SNP) | VAF 153/569 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ITPR1 | c.4965-2A>G p.X1655_splice (on ENST00000354582; = p.X1640_splice on NM_002222.7) | Splice Site (SNP) | VAF 193/762 reads (25%) | called by muse, mutect2, varscan2
- JMJD1C | c.1786T>C p.Y596H | Missense Mutation (SNP) | VAF 14/506 reads (3%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); called by muse, mutect2
- KCNA3 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 94/402 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- KIAA0100 | c.236G>A p.S79N | Missense Mutation (SNP) | VAF 147/641 reads (23%) | SIFT tolerated (0.87); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIF5C | c.2291A>G p.E764G | Missense Mutation (SNP) | VAF 68/869 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2
- KLHDC7A | c.1195G>T p.G399C | Missense Mutation (SNP) | VAF 119/443 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- KLHL13 | c.973C>T p.Q325* | Nonsense Mutation (SNP) | VAF 29/588 reads (5%) | called by muse, mutect2
- KMT2C | c.3712G>T p.E1238* | Nonsense Mutation (SNP) | VAF 88/325 reads (27%) | called by mutect2, varscan2
- KNG1 | c.1790G>A p.G597D | Missense Mutation (SNP) | VAF 112/628 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.054); called by muse, varscan2
- KRT2 | c.575T>C p.F192S | Missense Mutation (SNP) | VAF 36/590 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KRTAP9-9 | c.193A>G p.T65A | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT tolerated (0.18); called by muse, mutect2, varscan2
- LAIR1 | c.731G>A p.G244E | Missense Mutation (SNP) | VAF 71/499 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- LATS1 | c.2179A>G p.T727A | Missense Mutation (SNP) | VAF 195/699 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- LHFPL1 | c.278C>A p.A93D | Missense Mutation (SNP) | VAF 22/484 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.097); called by muse, mutect2
- LRCH3 | c.1121A>C p.Q374P | Missense Mutation (SNP) | VAF 248/890 reads (28%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- LRRIQ1 | c.2377G>A p.D793N | Missense Mutation (SNP) | VAF 63/227 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP6 | c.695G>A p.G232E | Missense Mutation (SNP) | VAF 42/287 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- MARCOL | c.731G>A p.S244N | Missense Mutation (SNP) | VAF 222/488 reads (45%) | SIFT tolerated (0.67); PolyPhen benign (0.275); called by muse, varscan2
- MAST2 | c.2178del p.F726Lfs*12 | Frame Shift Del (DEL) | VAF 205/703 reads (29%) | called by mutect2, varscan2
- MCHR1 | c.197G>A p.G66D | Missense Mutation (SNP) | VAF 26/326 reads (8%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); called by muse, mutect2
- MDN1 | c.15052G>A p.E5018K | Missense Mutation (SNP) | VAF 177/786 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- MDN1 | c.4901T>C p.V1634A | Missense Mutation (SNP) | VAF 150/712 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- MMP1 | c.395A>G p.H132R | Missense Mutation (SNP) | VAF 148/632 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- MON1A | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 219/927 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- MS4A15 | c.614C>A p.P205H (on ENST00000405633 / NM_001098835.2; = p.P112H on NM_152717.3) | Missense Mutation (SNP) | VAF 67/558 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- MS4A6E | c.424C>T p.Q142* | Nonsense Mutation (SNP) | VAF 128/487 reads (26%) | called by muse, varscan2
- MUC16 | c.32870G>A p.G10957D | Missense Mutation (SNP) | VAF 14/360 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.8); called by muse, mutect2
- MYC | c.580G>A p.V194I (on ENST00000377970; = p.V209I on NM_002467.6) | Missense Mutation (SNP) | VAF 80/273 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- MYH10 | c.1958T>A p.V653D | Missense Mutation (SNP) | VAF 60/480 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYH14 | c.786+1G>A p.X262_splice | Splice Site (SNP) | VAF 88/441 reads (20%) | called by muse, mutect2, varscan2
- MYO10 | c.3377G>A p.G1126E | Missense Mutation (SNP) | VAF 152/828 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- NABP2 | c.355C>T p.Q119* | Nonsense Mutation (SNP) | VAF 177/636 reads (28%) | called by muse, mutect2, varscan2
- NCAPD3 | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 158/634 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NCOR1 | c.1573dup p.T525Nfs*11 | Frame Shift Ins (INS) | VAF 96/289 reads (33%) | called by mutect2, varscan2
- NCR2 | c.470C>A p.P157H | Missense Mutation (SNP) | VAF 157/580 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- NF1 | c.831T>G p.C277W | Missense Mutation (SNP) | VAF 96/729 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- NFRKB | c.1318G>T p.A440S (on ENST00000446488 / NM_001143835.2; = p.A465S on NM_006165.3) | Missense Mutation (SNP) | VAF 14/386 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.207); called by muse, mutect2
- NLN | c.1611G>T p.W537C | Missense Mutation (SNP) | VAF 42/949 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NRF1 | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 123/546 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- NRXN2 | c.2924T>C p.I975T | Missense Mutation (SNP) | VAF 146/549 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- NUP62 | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 35/190 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OCIAD1 | c.696del p.E233Kfs*4 | Frame Shift Del (DEL) | VAF 117/440 reads (27%) | called by mutect2, varscan2
- OR1N2 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 103/377 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- OR2T6 | c.671C>T p.T224I | Missense Mutation (SNP) | VAF 159/569 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- OR5K3 | c.716G>A p.C239Y | Missense Mutation (SNP) | VAF 25/601 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR7A10 | c.163C>A p.L55I | Missense Mutation (SNP) | VAF 30/265 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- OSBPL1A | c.1007G>A p.S336N | Missense Mutation (SNP) | VAF 44/704 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- PARP16 | c.648G>T p.E216D | Missense Mutation (SNP) | VAF 36/419 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- PCDHB10 | c.1305C>G p.H435Q | Missense Mutation (SNP) | VAF 189/486 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- PCDHB2 | c.1311C>G p.H437Q | Missense Mutation (SNP) | VAF 122/1566 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.082); called by muse, mutect2
- PCDHB6 | c.2072C>T p.A691V | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PCDHB8 | c.1495C>A p.L499M | Missense Mutation (SNP) | VAF 54/302 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.517); called by muse, mutect2
- PCDHGA2 | c.1954C>T p.P652S | Missense Mutation (SNP) | VAF 41/252 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PCDHGB5 | c.177G>T p.Q59H | Missense Mutation (SNP) | VAF 43/404 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PDE6D | c.354G>A p.M118I | Missense Mutation (SNP) | VAF 158/649 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.005); called by muse, varscan2
- PDZRN4 | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 71/251 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- PEX19 | c.612G>T p.Q204H | Missense Mutation (SNP) | VAF 246/1060 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- PIK3R6 | c.1198C>T p.P400S | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.416); called by muse, mutect2
- PIP4P2 | c.178G>A p.V60M | Missense Mutation (SNP) | VAF 38/1086 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- PKD1L3 | c.3336G>T p.Q1112H | Missense Mutation (SNP) | VAF 177/859 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); called by mutect2, varscan2
- PLA2G2F | c.484C>A p.L162M | Missense Mutation (SNP) | VAF 134/555 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PMEPA1 | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 15/274 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PMEPA1 | c.610G>A p.G204S | Missense Mutation (SNP) | VAF 82/568 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- PNPLA6 | c.1973G>T p.R658M (on ENST00000414982 / NM_001166111.2; = p.R610M on NM_006702.5) | Missense Mutation (SNP) | VAF 63/233 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- PNPLA6 | c.3240+4G>T | Splice Region (SNP) | VAF 80/291 reads (27%) | called by muse, mutect2, varscan2
- POLE | c.6651G>T p.Q2217H | Missense Mutation (SNP) | VAF 129/474 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPME1 | c.317G>T p.R106M | Missense Mutation (SNP) | VAF 107/511 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PPP1R37 | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 77/539 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- PRDM2 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 62/984 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- PRR14L | c.288C>G p.D96E | Missense Mutation (SNP) | VAF 20/484 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.412); called by muse, mutect2
- PRRC2C | c.4855G>A p.G1619R (on ENST00000367742; = p.G1617R on NM_015172.4) | Missense Mutation (SNP) | VAF 33/629 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.726); called by muse, mutect2
- PSMD2 | c.2225C>T p.A742V | Missense Mutation (SNP) | VAF 133/516 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); called by muse, varscan2
- PSME1 | c.618G>T p.E206D | Missense Mutation (SNP) | VAF 135/576 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- PURG | c.541A>G p.R181G | Missense Mutation (SNP) | VAF 78/474 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- PXDN | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 86/417 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- R3HDM1 | c.1400G>A p.S467N | Missense Mutation (SNP) | VAF 24/866 reads (3%) | SIFT tolerated (0.33); PolyPhen benign (0.015); called by muse, mutect2
- RANBP17 | c.2038+1G>A p.X680_splice | Splice Site (SNP) | VAF 174/615 reads (28%) | called by muse, mutect2, varscan2
- RBBP4 | c.173G>T p.G58V | Missense Mutation (SNP) | VAF 44/608 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.154); called by muse, mutect2
- RBBP6 | c.4037C>T p.A1346V | Missense Mutation (SNP) | VAF 328/828 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBM45 | c.994C>A p.L332I (on ENST00000616198 / NM_001365579.1; = p.L330I on NM_152945.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 100/404 reads (25%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, varscan2
- RD3 | c.383G>T p.R128M | Missense Mutation (SNP) | VAF 142/543 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- RIC1 | c.3136A>G p.R1046G | Missense Mutation (SNP) | VAF 30/613 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.038); called by muse, mutect2
- ROBO2 | c.3298G>A p.D1100N | Missense Mutation (SNP) | VAF 167/680 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- RRBP1 | c.359C>A p.P120H | Missense Mutation (SNP) | VAF 32/682 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RTL5 | c.937G>A p.V313I | Missense Mutation (SNP) | VAF 216/650 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, varscan2
- SARDH | c.1844G>A p.G615E | Missense Mutation (SNP) | VAF 75/298 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- SARDH | c.1264C>T p.Q422* | Nonsense Mutation (SNP) | VAF 84/380 reads (22%) | called by muse, mutect2, varscan2
- SART1 | c.1970A>G p.K657R | Missense Mutation (SNP) | VAF 113/433 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- SBNO2 | c.598G>T p.E200* | Nonsense Mutation (SNP) | VAF 45/218 reads (21%) | called by muse, mutect2, varscan2
- SDK1 | c.2594T>C p.L865S | Missense Mutation (SNP) | VAF 17/548 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); called by muse, mutect2
- SEC24C | c.916T>G p.F306V | Missense Mutation (SNP) | VAF 210/762 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- SELENOS | c.318+1G>T p.X106_splice | Splice Site (SNP) | VAF 117/503 reads (23%) | called by muse, mutect2, varscan2
- SEMA4C | c.1537C>T p.R513W | Missense Mutation (SNP) | VAF 135/485 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEMA5A | c.1986G>T p.W662C | Missense Mutation (SNP) | VAF 53/1131 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- SETBP1 | c.3026G>T p.R1009M | Missense Mutation (SNP) | VAF 268/815 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SF3B1 | c.666G>T p.E222D | Missense Mutation (SNP) | VAF 96/372 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- SGSM1 | c.2879A>C p.K960T (on ENST00000400359 / NM_001039948.4; = p.K899T on NM_133454.3) | Missense Mutation (SNP) | VAF 122/707 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SKOR2 | c.979G>A p.A327T | Missense Mutation (SNP) | VAF 92/401 reads (23%) | SIFT tolerated, low confidence (0.56); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- SLC1A4 | c.1243G>T p.A415S | Missense Mutation (SNP) | VAF 24/316 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SLC22A14 | c.1498C>A p.L500I | Missense Mutation (SNP) | VAF 151/587 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SLC45A4 | c.1147G>T p.V383F (on ENST00000517878 / NM_001286646.2; = p.V332F on NM_001080431.2) | Missense Mutation (SNP) | VAF 20/406 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.169); called by muse, mutect2
- SLC9B2 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 100/457 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- SLIT2 | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 146/502 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SMC5 | c.542A>G p.Q181R | Missense Mutation (SNP) | VAF 72/257 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- SOS2 | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 77/404 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- SOX21 | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 59/160 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPATA12 | c.553C>T p.H185Y | Missense Mutation (SNP) | VAF 90/394 reads (23%) | SIFT tolerated, low confidence (0.79); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- SPECC1L | c.1040G>A p.S347N | Missense Mutation (SNP) | VAF 20/382 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SPEF2 | c.3326T>C p.V1109A | Missense Mutation (SNP) | VAF 154/856 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- SPRYD4 | c.524C>T p.T175M | Missense Mutation (SNP) | VAF 65/276 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- SRRM5 | c.1940C>A p.P647H | Missense Mutation (SNP) | VAF 20/415 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.06); called by muse, mutect2
- STARD5 | c.148C>T p.L50= | Splice Region (SNP) | VAF 104/407 reads (26%) | called by muse, mutect2, varscan2
- STC2 | c.889T>C p.Y297H | Missense Mutation (SNP) | VAF 27/1078 reads (3%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.339); called by muse, mutect2
- SYNE4 | c.536T>A p.I179N | Missense Mutation (SNP) | VAF 77/349 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- TASOR | c.949G>A p.V317I | Missense Mutation (SNP) | VAF 142/590 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TBC1D17 | c.642C>T p.R214= | Splice Region (SNP) | VAF 109/452 reads (24%) | called by muse, mutect2, varscan2
- TEC | c.1472C>T p.A491V | Missense Mutation (SNP) | VAF 26/620 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, mutect2
- TEK | c.1919C>A p.P640H | Missense Mutation (SNP) | VAF 113/497 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TGIF1 | c.289A>C p.I97L (on ENST00000330513 / NM_001374396.1; = p.I117L on NM_003244.4) | Missense Mutation (SNP) | VAF 171/723 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TJP2 | c.2667+5G>A | Splice Region (SNP) | VAF 146/502 reads (29%) | called by muse, mutect2, varscan2
- TMEM161B | c.728del p.L243* | Frame Shift Del (DEL) | VAF 64/642 reads (10%) | called by mutect2, varscan2
- TMEM202 | c.397C>A p.L133I | Missense Mutation (SNP) | VAF 110/542 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- TMEM231 | c.839T>C p.F280S (on ENST00000258173 / NM_001077418.3; = p.F309S on NM_001077416.2) | Missense Mutation (SNP) | VAF 286/756 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.818); called by muse, varscan2
- TRIM65 | c.496A>T p.S166C | Missense Mutation (SNP) | VAF 74/523 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- TRIP12 | c.1024C>A p.L342M | Missense Mutation (SNP) | VAF 24/590 reads (4%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.979); called by muse, mutect2
- TSC22D1 | c.3214A>G p.T1072A (on ENST00000458659 / NM_183422.4; = p.T143A on NM_006022.4) | Missense Mutation (SNP) | VAF 22/454 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.112); called by muse, mutect2
- TUBGCP5 | c.2889G>A p.M963I | Missense Mutation (SNP) | VAF 94/459 reads (20%) | SIFT tolerated (0.84); PolyPhen benign (0.003); called by muse, varscan2
- TWF2 | c.237G>T p.Q79H | Missense Mutation (SNP) | VAF 185/512 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- UBA5 | c.725del p.K242Rfs*3 | Frame Shift Del (DEL) | VAF 136/520 reads (26%) | called by mutect2, varscan2
- UBXN11 | c.721G>T p.G241C (on ENST00000374221 / NM_183008.2; = p.G208C on NM_145345.2) | Missense Mutation (SNP) | VAF 187/677 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USF2 | c.1013A>T p.E338V | Missense Mutation (SNP) | VAF 64/403 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.082); called by muse, mutect2
- VAV1 | c.2276C>T p.T759I | Missense Mutation (SNP) | VAF 189/768 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WDFY4 | c.2351T>C p.L784P | Missense Mutation (SNP) | VAF 20/462 reads (4%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.77); called by muse, mutect2
- WNT10A | c.1178A>G p.H393R | Missense Mutation (SNP) | VAF 65/288 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- WWP1 | c.278T>C p.L93S | Missense Mutation (SNP) | VAF 116/438 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, varscan2
- XIRP2 | c.560C>T p.T187I (on ENST00000628543; = p.T362I on NM_152381.6) | Missense Mutation (SNP) | VAF 93/570 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- ZBTB17 | c.1589G>A p.C530Y | Missense Mutation (SNP) | VAF 71/273 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ZBTB8B | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 84/310 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- ZFHX3 | c.1039T>C p.F347L | Missense Mutation (SNP) | VAF 39/554 reads (7%) | SIFT tolerated (0.95); PolyPhen possibly damaging (0.713); called by muse, mutect2
- ZNF135 | c.26C>T p.T9I | Missense Mutation (SNP) | VAF 79/301 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZNF215 | c.1240A>T p.R414* | Nonsense Mutation (SNP) | VAF 63/487 reads (13%) | called by muse, mutect2, varscan2
- ZNF215 | c.1482A>T p.E494D | Missense Mutation (SNP) | VAF 60/591 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ZNF414 | c.586C>T p.H196Y | Missense Mutation (SNP) | VAF 119/480 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZNF518B | c.397G>T p.G133C | Missense Mutation (SNP) | VAF 28/888 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF532 | c.1028G>A p.S343N | Missense Mutation (SNP) | VAF 199/540 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- ZNF540 | c.1842G>T p.K614N | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZNF615 | c.485G>T p.G162V | Missense Mutation (SNP) | VAF 109/448 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by mutect2, varscan2
- ZNF646 | c.3101A>G p.D1034G | Missense Mutation (SNP) | VAF 59/610 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZNF654 | c.122G>A p.G41D | Missense Mutation (SNP) | VAF 93/375 reads (25%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZNF837 | c.1096G>A p.A366T | Missense Mutation (SNP) | VAF 60/229 reads (26%) | SIFT tolerated (0.97); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ACTR1B | c.744G>A p.T248= | Silent (SNP) | VAF 115/461 reads (25%) | catalogued as rs373737375; called by muse, mutect2, varscan2
- ADAR | c.2250C>T p.S750= | Silent (SNP) | VAF 129/523 reads (25%) | catalogued as rs746605003, CD150583; called by muse, mutect2, varscan2
- ADARB2 | c.847C>T p.L283= | Silent (SNP) | VAF 34/450 reads (8%) | called by muse, mutect2
- ADCY3 | c.1122C>T p.C374= | Silent (SNP) | VAF 187/696 reads (27%) | catalogued as rs773307411; called by muse, mutect2, varscan2
- ADGRA1 | c.417C>T p.S139= | Silent (SNP) | VAF 151/609 reads (25%) | catalogued as COSV66925348; called by muse, mutect2, varscan2
- AGO4 | c.855T>G p.P285= | Silent (SNP) | VAF 52/492 reads (11%) | called by muse, mutect2, varscan2
- AGRN | c.3006C>T p.G1002= | Silent (SNP) | VAF 47/236 reads (20%) | catalogued as rs774744948; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AHDC1 | c.4569G>C p.R1523= | Silent (SNP) | VAF 78/411 reads (19%) | called by muse, mutect2, varscan2
- AJAP1 | c.861C>T p.T287= | Silent (SNP) | VAF 148/729 reads (20%) | catalogued as rs370080285; called by muse, varscan2
- ALDH1A1 | c.1443C>T p.Y481= | Silent (SNP) | VAF 38/504 reads (8%) | catalogued as rs1393382260; called by muse, mutect2
- ANKRD36 | c.612T>C p.A204= | Silent (SNP) | VAF 176/717 reads (25%) | called by muse, mutect2, varscan2
- AP1G2 | c.1479C>T p.C493= | Silent (SNP) | VAF 83/439 reads (19%) | catalogued as rs942180344; called by muse, mutect2, varscan2
- ARHGEF38 | c.2004C>T p.F668= | Silent (SNP) | VAF 187/790 reads (24%) | catalogued as rs534216698; called by muse, mutect2, varscan2
- BACE1 | c.682C>T p.L228= | Silent (SNP) | VAF 199/828 reads (24%) | catalogued as rs1257740333; called by muse, mutect2, varscan2
- BAZ1A | c.2241A>G p.K747= | Silent (SNP) | VAF 95/289 reads (33%) | called by muse, mutect2, varscan2
- BCL11B | c.2586C>A p.P862= (on ENST00000357195 / NM_001282237.2; = p.P791= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 100/394 reads (25%) | catalogued as COSV100595157, COSV61740111; called by muse, mutect2, varscan2
- BCL6B | c.1203G>A p.A401= | Silent (SNP) | VAF 69/186 reads (37%) | catalogued as rs748891591, COSV53428900; called by muse, mutect2, varscan2
- BIRC6 | c.2556C>A p.P852= | Silent (SNP) | VAF 136/531 reads (26%) | called by mutect2, varscan2
- BRINP1 | c.1500C>T p.Y500= | Silent (SNP) | VAF 104/385 reads (27%) | catalogued as rs142482414, COSV56316943; called by muse, mutect2, varscan2
- C11orf65 | c.774G>A p.S258= | Silent (SNP) | VAF 140/620 reads (23%) | catalogued as rs369410173; called by muse, mutect2, varscan2
- CABIN1 | c.5979C>T p.D1993= | Silent (SNP) | VAF 78/554 reads (14%) | called by muse, mutect2, varscan2
- CABP7 | c.276G>A p.E92= | Silent (SNP) | VAF 184/696 reads (26%) | called by muse, mutect2, varscan2
- CAMKK2 | c.1050G>A p.T350= | Silent (SNP) | VAF 186/661 reads (28%) | catalogued as rs1378357800; called by muse, mutect2, varscan2
- CAPN10 | c.1899C>T p.D633= | Silent (SNP) | VAF 67/341 reads (20%) | called by muse, mutect2, varscan2
- CDH4 | c.1599C>T p.D533= | Silent (SNP) | VAF 29/824 reads (4%) | catalogued as rs1360115740; called by muse, mutect2
- CEL | c.1983C>T p.P661= (on ENST00000673714; = p.P658= on NM_001807.6) | Silent (SNP) | VAF 22/168 reads (13%) | catalogued as rs1371362530, COSV60827872; called by muse, varscan2
- CELSR1 | c.993G>A p.P331= | Silent (SNP) | VAF 76/275 reads (28%) | catalogued as rs201209154; called by muse, mutect2, varscan2
- CEP250 | c.6987G>A p.T2329= | Silent (SNP) | VAF 107/379 reads (28%) | catalogued as rs765020383, COSV100699243; called by muse, varscan2
- CGNL1 | c.3351C>T p.C1117= | Silent (SNP) | VAF 47/302 reads (16%) | catalogued as rs769938496; called by muse, mutect2, varscan2
- CIC | c.693C>T p.G231= | Silent (SNP) | VAF 128/471 reads (27%) | called by muse, mutect2, varscan2
- CILP2 | c.957C>A p.P319= | Silent (SNP) | VAF 65/323 reads (20%) | called by muse, mutect2, varscan2
- CLPB | c.1338C>T p.C446= | Silent (SNP) | VAF 134/579 reads (23%) | called by muse, varscan2
- CNOT3 | c.1038C>T p.P346= | Silent (SNP) | VAF 12/344 reads (3%) | catalogued as rs750701546; called by muse, mutect2
- COL4A1 | c.2217G>A p.P739= | Silent (SNP) | VAF 132/606 reads (22%) | catalogued as rs756617734, COSV65432243; called by muse, mutect2, varscan2
- CTTNBP2 | c.3102C>T p.D1034= | Silent (SNP) | VAF 112/559 reads (20%) | catalogued as rs752008933, COSV50402414; called by muse, mutect2, varscan2
- CYB5R4 | c.1398A>G p.K466= | Silent (SNP) | VAF 133/690 reads (19%) | called by muse, mutect2, varscan2
- CYLD | c.411T>G p.S137= | Silent (SNP) | VAF 24/745 reads (3%) | called by muse, mutect2
- DBH | c.1662C>T p.A554= | Silent (SNP) | VAF 112/651 reads (17%) | called by muse, mutect2, varscan2
- DCLRE1A | c.2130C>T p.T710= | Silent (SNP) | VAF 84/381 reads (22%) | catalogued as rs182063175; called by muse, mutect2, varscan2
- DEF8 | c.1020G>A p.A340= | Silent (SNP) | VAF 153/396 reads (39%) | catalogued as rs140137747; called by muse, mutect2, varscan2
- DGCR2 | c.516C>T p.P172= | Silent (SNP) | VAF 176/697 reads (25%) | catalogued as rs367994263, COSV99593274; called by muse, mutect2, varscan2
- DGCR2 | c.315C>T p.P105= | Silent (SNP) | VAF 218/754 reads (29%) | catalogued as rs747592522, COSV99593612, COSV99594085; called by muse, mutect2, varscan2
- DGKD | c.2130C>T p.D710= (on ENST00000264057 / NM_152879.3; = p.D666= on NM_003648.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 160/680 reads (24%) | catalogued as rs747461841, COSV51081587; called by muse, varscan2
- DLGAP5 | c.525C>T p.I175= | Silent (SNP) | VAF 40/688 reads (6%) | called by muse, mutect2
- DOK6 | c.105T>C p.S35= | Silent (SNP) | VAF 102/502 reads (20%) | called by muse, mutect2, varscan2
- DOT1L | c.4410G>A p.P1470= | Silent (SNP) | VAF 78/343 reads (23%) | catalogued as rs778682125, COSV101288799; called by muse, mutect2, varscan2
- DSCAM | c.3510C>T p.R1170= | Silent (SNP) | VAF 187/798 reads (23%) | catalogued as rs370692788; called by muse, mutect2, varscan2
- DSEL | c.864C>A p.A288= | Silent (SNP) | VAF 28/628 reads (4%) | called by muse, mutect2
- DYNC1H1 | c.1671C>A p.I557= | Silent (SNP) | VAF 122/398 reads (31%) | catalogued as COSV64141711; called by muse, mutect2, varscan2
- DYNC1H1 | c.8751C>T p.D2917= | Silent (SNP) | VAF 169/634 reads (27%) | called by muse, mutect2, varscan2
- DZIP3 | c.213C>T p.H71= | Silent (SNP) | VAF 52/291 reads (18%) | called by muse, mutect2, varscan2
- EFEMP1 | c.636C>T p.C212= | Silent (SNP) | VAF 95/363 reads (26%) | catalogued as rs771544911; called by muse, mutect2, varscan2
- EFHB | c.450C>T p.G150= | Silent (SNP) | VAF 107/500 reads (21%) | called by muse, mutect2, varscan2
- EIF5 | c.711G>A p.E237= | Silent (SNP) | VAF 130/507 reads (26%) | catalogued as rs1336451265; called by muse, mutect2, varscan2
- EIF6 | c.562C>A p.R188= | Silent (SNP) | VAF 268/861 reads (31%) | called by muse, mutect2, varscan2
- EN2 | c.183G>A p.Q61= | Silent (SNP) | VAF 8/128 reads (6%) | called by muse, mutect2
- EPS15 | c.2283G>A p.S761= | Silent (SNP) | VAF 68/914 reads (7%) | catalogued as rs147463788, COSV65544872; called by muse, mutect2
- ETV6 | c.792C>T p.R264= | Silent (SNP) | VAF 75/347 reads (22%) | catalogued as rs1422938391, COSV101122435; called by muse, mutect2, varscan2
- FABP1 | c.117G>A p.S39= | Silent (SNP) | VAF 182/679 reads (27%) | catalogued as rs770387493, COSV55557805; called by muse, mutect2, varscan2
- FAM214A | c.534C>T p.I178= | Silent (SNP) | VAF 49/424 reads (12%) | called by muse, mutect2, varscan2
- FBRS | c.969T>C p.A323= (on ENST00000287468; = p.A843= on NM_001105079.3) | Silent (SNP) | VAF 81/645 reads (13%) | catalogued as rs932251061; called by muse, mutect2, varscan2
- FLNB | c.2772C>T p.Y924= | Silent (SNP) | VAF 172/617 reads (28%) | catalogued as rs370142959; called by muse, varscan2
- FLNC | c.5934C>T p.T1978= | Silent (SNP) | VAF 111/362 reads (31%) | catalogued as rs182514003; called by muse, mutect2, varscan2
- FNTB | c.627C>A p.S209= | Silent (SNP) | VAF 127/488 reads (26%) | catalogued as COSV55764760; called by muse, mutect2, varscan2
- FTCD | c.1314G>A p.A438= | Silent (SNP) | VAF 108/410 reads (26%) | catalogued as rs777750537, COSV52425455; ClinVar: likely benign; called by muse, mutect2, varscan2
- GAN | c.756G>A p.P252= | Silent (SNP) | VAF 160/674 reads (24%) | catalogued as rs138585506; called by muse, mutect2, varscan2
- GBE1 | c.1965G>A p.A655= | Silent (SNP) | VAF 49/647 reads (8%) | catalogued as rs762480067; called by muse, mutect2
- GDPD5 | c.804C>T p.D268= | Silent (SNP) | VAF 37/282 reads (13%) | catalogued as rs745329093, COSV100408954; called by muse, mutect2, varscan2
- GJA10 | c.1332C>T p.H444= | Silent (SNP) | VAF 74/265 reads (28%) | called by muse, mutect2, varscan2
- GJA3 | c.1092C>T p.H364= | Silent (SNP) | VAF 137/465 reads (29%) | catalogued as rs1027325918, COSV99078602; called by muse, mutect2, varscan2
- GLI1 | c.2976G>A p.L992= | Silent (SNP) | VAF 26/296 reads (9%) | called by muse, mutect2
- GMNN | c.579G>A p.T193= | Silent (SNP) | VAF 36/504 reads (7%) | catalogued as rs373551106, COSV57777419; called by muse, mutect2
- GRAMD2B | c.1132C>T p.L378= | Silent (SNP) | VAF 236/886 reads (27%) | called by muse, mutect2, varscan2
- GRM7 | c.864C>T p.N288= | Silent (SNP) | VAF 217/944 reads (23%) | catalogued as rs1306855320, COSV100735892; called by muse, mutect2, varscan2
- GTF2IRD1 | c.2214C>T p.P738= (on ENST00000265755 / NM_016328.3; = p.P723= on NM_005685.4) | Silent (SNP) | VAF 153/481 reads (32%) | catalogued as rs782217257, COSV56086027; ClinVar: likely benign; called by muse, mutect2, varscan2
- H2AX | c.153C>T p.Y51= | Silent (SNP) | VAF 64/257 reads (25%) | catalogued as rs1387578530; called by muse, mutect2, varscan2
- HABP2 | c.51G>T p.V17= | Silent (SNP) | VAF 133/586 reads (23%) | called by muse, mutect2, varscan2
- HAS1 | c.1536G>A p.L512= | Silent (SNP) | VAF 53/334 reads (16%) | catalogued as rs1399094800; called by muse, mutect2, varscan2
- HDAC5 | c.1872T>C p.A624= | Silent (SNP) | VAF 56/286 reads (20%) | called by muse, mutect2, varscan2
- HDGFL2 | c.336C>T p.D112= | Silent (SNP) | VAF 151/621 reads (24%) | catalogued as rs371059610; called by muse, mutect2, varscan2
- HIRIP3 | c.354T>C p.N118= | Silent (SNP) | VAF 232/1254 reads (19%) | called by muse, mutect2, varscan2
- HIVEP2 | c.4143C>T p.N1381= | Silent (SNP) | VAF 76/280 reads (27%) | catalogued as rs538728299; called by muse, mutect2, varscan2
- HK2 | c.705C>T p.N235= | Silent (SNP) | VAF 160/644 reads (25%) | catalogued as rs746790240; called by muse, varscan2
- HMCN2 | c.9609C>T p.C3203= | Silent (SNP) | VAF 49/248 reads (20%) | catalogued as rs746126221; called by muse, mutect2, varscan2
- HRH3 | c.390C>T p.Y130= | Silent (SNP) | VAF 249/847 reads (29%) | catalogued as rs535352884; called by muse, mutect2, varscan2
- HSF5 | c.261C>T p.Y87= | Silent (SNP) | VAF 109/433 reads (25%) | catalogued as rs1188126892, COSV60204808; called by muse, mutect2, varscan2
- HSPA1L | c.1014A>G p.L338= | Silent (SNP) | VAF 15/395 reads (4%) | called by muse, mutect2
- HYAL2 | c.765C>T p.D255= | Silent (SNP) | VAF 94/296 reads (32%) | catalogued as rs200942332, COSV63305892; called by muse, mutect2, varscan2
379 further variants in this file (0 protein-altering or splice-affecting, 180 silent, 199 other) are not listed here.
